Somatic mutation profile of tumor specimen TCGA-FS-A1ZK-06A (aliquot TCGA-FS-A1ZK-06A-11D-A197-08) from TCGA case TCGA-FS-A1ZK, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 68.9 years (25,175 days).
Specimen TCGA-FS-A1ZK-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3d4a4a1b-9dbc-4020-ac49-e1266fcc58f0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FS-A1ZK-10A (Blood Derived Normal), aliquot TCGA-FS-A1ZK-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/40f9015a-0c2a-4ba0-ab8f-4d994cb1f8fc

The open-access MAF lists 1,888 somatic variants for this specimen: 1,202 protein-altering or splice-affecting, 659 silent, 27 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,086, Silent 659, Nonsense Mutation 69, Splice Region 20, Splice Site 20, Intron 9, RNA 6, Frame Shift Del 4, 5'Flank 4, 3'UTR 3, 5'UTR 3, In Frame Del 2.

Variants (750 of 1,888; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 50/53 reads (94%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SCN1A | c.2956C>T p.L986F (on ENST00000303395 / NM_001202435.3; = p.L975F on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121918625, CM034963, COSV57666493; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AADACL3 | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV60198683; called by muse, mutect2, varscan2
- ABCA12 | c.6248C>T p.S2083F (on ENST00000272895 / NM_173076.3; = p.S1765F on NM_015657.3) | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV55955359; called by muse, mutect2, varscan2
- ABCA13 | c.7020G>A p.M2340I | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs768266093, COSV71286073; called by muse, mutect2, varscan2
- ABCA13 | c.8525G>A p.R2842K | Missense Mutation (SNP) | VAF 49/129 reads (38%) | SIFT tolerated (0.42); PolyPhen benign (0.023); catalogued as COSV71286080, COSV71288716; called by muse, mutect2, varscan2
- ABCB11 | c.1978G>A p.G660R | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as COSV55586833; called by muse, mutect2, varscan2
- ABCB4 | c.2738G>A p.R913K | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated (0.74); PolyPhen benign (0.02); catalogued as rs1485784192, COSV55934156; called by muse, mutect2, varscan2
- ABCB5 | c.3362C>T p.P1121L (on ENST00000404938 / NM_001163941.2; = p.P676L on NM_178559.6) | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as COSV51707690; called by muse, mutect2, varscan2
- ABCC8 | c.2318C>T p.S773L | Missense Mutation (SNP) | VAF 120/280 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); catalogued as rs1355146733, COSV56846265; called by muse, mutect2, varscan2
- ABCG4 | c.1063C>T p.P355S | Missense Mutation (SNP) | VAF 56/62 reads (90%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV56643161; called by muse, mutect2, varscan2
- ABRA | c.469C>T p.P157S | Missense Mutation (SNP) | VAF 27/204 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.68); catalogued as COSV61732207; called by muse, mutect2, varscan2
- AC100868.1 | c.1301C>G p.T434S | Missense Mutation (SNP) | VAF 20/196 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.026); catalogued as COSV51841000; called by muse, mutect2
- ACKR2 | c.724C>T p.P242S | Missense Mutation (SNP) | VAF 46/178 reads (26%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.986); catalogued as COSV56177479; called by muse, mutect2, varscan2
- ACOT4 | c.929C>T p.P310L | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58335592; called by muse, mutect2, varscan2
- ACOX1 | c.1573C>T p.R525* | Nonsense Mutation (SNP) | VAF 16/93 reads (17%) | catalogued as rs771228961, COSV53132720; called by muse, mutect2, varscan2
- ACOX3 | c.1579C>T p.R527* | Nonsense Mutation (SNP) | VAF 31/202 reads (15%) | catalogued as rs146945288, COSV104423159; called by muse, mutect2, varscan2
- ACOX3 | c.865C>T p.P289S | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.009); catalogued as rs771763093, COSV62711613; called by muse, mutect2, varscan2
- ACSL6 | c.1070C>T p.A357V (on ENST00000379240; = p.A382V on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.013); catalogued as COSV57297016; called by muse, mutect2, varscan2
- ACSM1 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV54634765; called by muse, mutect2, varscan2
- ACSS3 | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.106); catalogued as rs914039814, COSV54089066; called by muse, mutect2, varscan2
- ACTN1 | c.2615C>T p.S872F | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.315); catalogued as rs745859336, COSV51990451; called by muse, mutect2, varscan2
- ADAM12 | c.1381G>A p.D461N | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.872); catalogued as rs200090925, COSV100900139; called by muse, mutect2, varscan2
- ADAM30 | c.2161G>A p.E721K | Missense Mutation (SNP) | VAF 220/751 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65560837; called by muse, mutect2, varscan2
- ADAM30 | c.1067G>A p.R356K | Missense Mutation (SNP) | VAF 228/810 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV65560846; called by muse, varscan2
- ADAMTS1 | c.2365G>C p.E789Q | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV53169775; called by muse, mutect2, varscan2
- ADAMTS19 | c.3071G>A p.R1024K | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs200004633, COSV50741828; called by muse, mutect2, varscan2
- ADAMTS20 | c.1471C>T p.L491F | Missense Mutation (SNP) | VAF 40/144 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.654); catalogued as COSV67130029; called by muse, mutect2, varscan2
- ADAMTS3 | c.1350C>T p.I450= | Splice Region (SNP) | VAF 27/53 reads (51%) | catalogued as COSV54389311; called by muse, mutect2, varscan2
- ADARB1 | c.565C>T p.P189S | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV62343622; called by muse, mutect2, varscan2
- ADCY5 | c.3713G>C p.R1238P | Missense Mutation (SNP) | VAF 37/156 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59196643; called by muse, mutect2, varscan2
- ADGRB1 | c.3968G>A p.G1323E | Missense Mutation (SNP) | VAF 29/217 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.904); catalogued as COSV60094638; called by muse, mutect2, varscan2
- ADGRB2 | c.2545C>T p.P849S | Missense Mutation (SNP) | VAF 25/156 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.262); catalogued as COSV57071868; called by muse, mutect2, varscan2
- ADGRB3 | c.2365G>A p.V789M | Missense Mutation (SNP) | VAF 34/36 reads (94%) | SIFT tolerated (0.08); PolyPhen benign (0.044); catalogued as rs373836331; called by muse, mutect2, varscan2
- ADGRD1 | c.501G>A p.W167* | Nonsense Mutation (SNP) | VAF 15/52 reads (29%) | catalogued as rs758546883; called by muse, mutect2, varscan2
- ADGRF1 | c.10G>A p.G4R | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.003); catalogued as COSV64799887; called by muse, mutect2, varscan2
- ADGRF2 | c.1550G>A p.G517E (on ENST00000296862 / NM_001368115.2; = p.G449E on NM_153839.7) | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.776); catalogued as COSV57287449; called by muse, mutect2, varscan2
- ADGRF4 | c.338C>T p.P113L | Missense Mutation (SNP) | VAF 28/266 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs149916768, COSV51951556; called by muse, mutect2, varscan2
- ADGRG3 | c.1364G>A p.W455* | Nonsense Mutation (SNP) | VAF 14/41 reads (34%) | catalogued as COSV59650779; called by muse, varscan2
- AFF3 | c.3635C>T p.S1212F | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV57866297; called by muse, mutect2, varscan2
- AGBL1 | c.1195G>A p.D399N | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.844); catalogued as rs1288221366, COSV66855080; called by muse, mutect2, varscan2
- AGPAT1 | c.290C>T p.P97L | Missense Mutation (SNP) | VAF 149/1461 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV61247419; called by muse, mutect2, varscan2
- AGXT2 | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 54/114 reads (47%) | SIFT tolerated (0.55); PolyPhen benign (0.026); catalogued as rs764792216, COSV104371058, COSV51485502; called by muse, mutect2, varscan2
- AHNAK | c.6118C>T p.H2040Y | Missense Mutation (SNP) | VAF 117/301 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.192); catalogued as COSV57210487; called by muse, mutect2, varscan2
- AHNAK | c.5629G>A p.V1877M | Missense Mutation (SNP) | VAF 60/145 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.299); catalogued as COSV57210502; called by muse, mutect2, varscan2
- AKAP6 | c.2860C>T p.H954Y | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV55211048, COSV99803963; called by muse, mutect2, varscan2
- AL645922.1 | c.1163C>T p.S388F | Missense Mutation (SNP) | VAF 162/1248 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as rs143869308; called by muse, varscan2
- ALDH7A1 | c.322C>T p.P108S | Missense Mutation (SNP) | VAF 33/142 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1369193908, COSV68628944; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALG14 | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.143); catalogued as COSV64634648; called by muse, varscan2
- ALPI | c.482C>T p.S161L | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55014229; called by muse, mutect2, varscan2
- ALPK3 | c.2240C>T p.P747L | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.994); catalogued as COSV51932335; called by muse, mutect2, varscan2
- AMDHD2 | c.857C>T p.P286L | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV53550410; called by muse, mutect2, varscan2
- ANK1 | c.964C>T p.R322W | Missense Mutation (SNP) | VAF 40/153 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs770743762, COSV55879029; called by muse, mutect2, varscan2
- ANK3 | c.10687G>A p.E3563K | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.073); catalogued as COSV55053099; called by muse, mutect2, varscan2
- ANK3 | c.4862C>T p.S1621F | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.467); catalogued as rs753360050, COSV55053119; called by muse, mutect2, varscan2
- ANKAR | c.3118C>T p.R1040C | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as rs149050269; called by muse, mutect2, varscan2
- ANKEF1 | c.1568A>T p.N523I | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.057); catalogued as COSV65692267; called by muse, mutect2, varscan2
- ANKMY1 | c.1607G>A p.R536Q | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as rs760526137, COSV56032798; called by muse, mutect2, varscan2
- ANKMY1 | c.1306C>T p.P436S | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.48); PolyPhen benign (0.006); catalogued as rs769318304, COSV56032278; called by muse, mutect2, varscan2
- ANKMY2 | c.824C>T p.P275L | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV61011479; called by muse, mutect2, varscan2
- ANKRD17 | c.6743C>T p.P2248L | Missense Mutation (SNP) | VAF 67/166 reads (40%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.01); catalogued as rs375736152; called by muse, mutect2, varscan2
- ANKRD33 | c.355C>T p.R119W (on ENST00000340970 / NM_001304459.2; = p.R244W on NM_182608.4) | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs764706850, COSV56605673; called by muse, mutect2, varscan2
- ANO7 | c.1486C>T p.R496C (on ENST00000274979; = p.R442C on NM_001370694.2) | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.377); catalogued as rs757887974, COSV51470633; called by muse, mutect2, varscan2
- ANTXR1 | c.1355G>A p.G452E | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV58012212; called by muse, mutect2, varscan2
- AP002748.5 | c.1648C>T p.P550S | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.67); catalogued as COSV59148072; called by muse, mutect2, varscan2
- APAF1 | c.1232T>C p.V411A (on ENST00000551964 / NM_181861.2; = p.V400A on NM_001160.3) | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as COSV59663323; called by muse, mutect2, varscan2
- APPL2 | c.976G>A p.D326N | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV51589701; called by muse, mutect2, varscan2
- APRT | c.401-1G>A p.X134_splice | Splice Site (SNP) | VAF 7/32 reads (22%) | catalogued as rs1441319199; called by muse, mutect2, varscan2
- ARAP1 | c.3625C>T p.R1209C (on ENST00000393609 / NM_001040118.2; = p.R964C on NM_015242.4) | Missense Mutation (SNP) | VAF 113/186 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.189); catalogued as rs1458415866, COSV61990074; called by muse, mutect2, varscan2
- AREL1 | c.1750T>A p.F584I | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV62666112; called by muse, mutect2, varscan2
- ARHGAP24 | c.1382G>A p.R461K (on ENST00000395184 / NM_001025616.3; = p.R368K on NM_031305.3) | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT tolerated (0.09); PolyPhen benign (0.192); catalogued as rs368930425; called by muse, mutect2, varscan2
- ARHGAP31 | c.1640C>T p.S547F | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV51791617; called by muse, mutect2, varscan2
- ARHGAP33 | c.3053C>T p.P1018L | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.258); catalogued as COSV50121710; called by muse, mutect2, varscan2
- ARHGEF11 | c.3287C>T p.P1096L | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.08); catalogued as rs767386127, COSV59353681; called by muse, mutect2, varscan2
- ARHGEF16 | c.1302G>A p.M434I | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV65681759; called by muse, mutect2, varscan2
- ARHGEF28 | c.45G>A p.M15I | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV55253466; called by muse, mutect2, varscan2
- ARID1A | c.2327C>T p.P776L | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.054); catalogued as COSV61375478, COSV61382995; called by muse, mutect2, varscan2
- ARID1A | c.3961C>T p.P1321S | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs774283518, COSV61375481; called by muse, mutect2, varscan2
- ARSK | c.1199C>T p.P400L | Missense Mutation (SNP) | VAF 81/203 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.416); catalogued as COSV66169502; called by muse, mutect2, varscan2
- ASCC3 | c.362C>T p.P121L | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT deleterious (0.03); PolyPhen benign (0.185); catalogued as COSV61227717; called by muse, mutect2, varscan2
- ASH1L | c.2627C>T p.S876F | Missense Mutation (SNP) | VAF 139/201 reads (69%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.466); catalogued as COSV64211515; called by muse, mutect2, varscan2
- ASMT | c.925G>A p.G309R (on ENST00000381229; = p.G337R on NM_004043.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67109773; called by muse, mutect2, varscan2
- ASRGL1 | c.752C>T p.S251L | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs1281984139, COSV57124024; called by muse, mutect2, varscan2
- ASXL3 | c.5335C>T p.P1779S | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.997); catalogued as rs769336687, COSV52463252; called by muse, mutect2, varscan2
- ATAD2B | c.3262T>A p.S1088T | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.547); catalogued as COSV53197261; called by muse, mutect2, varscan2
- ATF6B | c.425C>T p.S142F | Missense Mutation (SNP) | VAF 231/1448 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV100913558, COSV64322408; called by muse, mutect2, varscan2
- ATP10D | c.719C>T p.S240F | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.246); catalogued as COSV56706475; called by muse, mutect2, varscan2
- ATP1A2 | c.2116G>A p.G706R | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759387594, COSV63403337; called by muse, mutect2, varscan2
- ATP1A4 | c.611G>A p.G204E | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63626155; called by muse, mutect2, varscan2
- ATP2A3 | c.1715G>A p.R572K | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs112116136; called by muse, mutect2, varscan2
- ATP2B1 | c.1877C>T p.P626L | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.463); catalogued as COSV53806414; called by muse, mutect2, varscan2
- ATP5PF | c.32C>T p.S11F | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV53166795, COSV53166867; called by muse, mutect2, varscan2
- ATP7A | c.4138A>G p.I1380V | Missense Mutation (SNP) | VAF 70/88 reads (80%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as rs934280694, COSV58444909; called by muse, mutect2, varscan2
- ATP8A2 | c.1778G>A p.G593E | Missense Mutation (SNP) | VAF 49/133 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54947019; called by muse, mutect2, varscan2
- ATP9A | c.2608C>T p.P870S | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV58765252; called by muse, mutect2, varscan2
- ATXN1 | c.368T>G p.L123R | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV55213847; called by muse, mutect2, varscan2
- AXIN1 | c.1025G>A p.G342E | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV51986052; called by muse, mutect2, varscan2
- BACH2 | c.1204G>A p.V402M | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs757228508, COSV57589767, COSV57604018; called by muse, mutect2, varscan2
- BAG6 | c.296C>A p.S99Y | Missense Mutation (SNP) | VAF 63/1187 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.552); catalogued as COSV52989654; called by muse, mutect2
- BANK1 | c.2344A>G p.K782E | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.037); catalogued as COSV59841481; called by muse, mutect2, varscan2
- BATF | c.310C>T p.P104S | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.078); catalogued as COSV54375653; called by muse, mutect2, varscan2
- BCO1 | c.320C>T p.S107F | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.038); catalogued as COSV50728197; called by muse, mutect2, varscan2
- BDKRB2 | c.1058A>C p.K353T | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.118); catalogued as COSV60014360; called by muse, mutect2, varscan2
- BOD1L1 | c.2891C>T p.P964L | Missense Mutation (SNP) | VAF 72/550 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.039); catalogued as COSV50009631; called by muse, mutect2, varscan2
- BPIFB4 | c.491G>A p.G164E | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.994); catalogued as rs1389106912, COSV64951015; called by muse, mutect2, varscan2
- BRD1 | c.1244G>A p.S415N | Missense Mutation (SNP) | VAF 69/311 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.034); catalogued as COSV53456317; called by muse, mutect2, varscan2
- BRINP1 | c.2242G>A p.E748K | Missense Mutation (SNP) | VAF 75/179 reads (42%) | SIFT tolerated (1); PolyPhen possibly damaging (0.522); catalogued as COSV56297364; called by muse, mutect2, varscan2
- BSN | c.4949G>A p.G1650E | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56516027; called by muse, mutect2, varscan2
- BSN | c.9161C>T p.P3054L | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.52); PolyPhen benign (0.006); catalogued as rs1223112439, COSV56516039; called by muse, mutect2, varscan2
- BSN | c.11645G>A p.G3882E | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.154); catalogued as COSV56516050; called by muse, varscan2
- BTBD11 | c.3274C>T p.Q1092* (on ENST00000280758 / NM_001018072.2; = p.Q629* on NM_001017523.2) | Nonsense Mutation (SNP) | VAF 33/115 reads (29%) | catalogued as COSV55022087; called by muse, mutect2, varscan2
- C12orf40 | c.397G>A p.D133N | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV61131215; called by muse, mutect2, varscan2
- C19orf44 | c.826A>C p.T276P | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV55611716; called by muse, mutect2, varscan2
- C1QTNF1 | c.359G>A p.G120E | Missense Mutation (SNP) | VAF 58/96 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764031936; called by muse, mutect2, varscan2
- C1R | c.335A>G p.N112S (on ENST00000536053 / NM_001354346.2; = p.N98S on NM_001733.7) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.023); catalogued as COSV56924375; called by muse, mutect2
- C1orf158 | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 54/210 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); catalogued as rs1182872767, COSV55346524; called by muse, mutect2, varscan2
- C1orf94 | c.1702C>T p.L568F (on ENST00000488417 / NM_001134734.2; = p.L378F on NM_032884.5) | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.936); catalogued as rs763256041, COSV64913708; called by muse, mutect2
- C2CD5 | c.2398C>T p.Q800* | Nonsense Mutation (SNP) | VAF 27/52 reads (52%) | catalogued as COSV61724059; called by muse, mutect2, varscan2
- C2orf16 | c.1447G>A p.D483N | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.057); catalogued as COSV68645545, COSV68645863; called by muse, mutect2, varscan2
- C3orf20 | c.871C>T p.R291C | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.112); catalogued as rs370224298; called by muse, mutect2, varscan2
- C3orf20 | c.961C>T p.H321Y | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.784); catalogued as COSV53784418, COSV53784677; called by muse, mutect2, varscan2
- C5orf34 | c.1130C>T p.S377F | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.135); catalogued as COSV60929564, COSV60930062; called by muse, mutect2, varscan2
- C6orf15 | c.458G>A p.G153E | Missense Mutation (SNP) | VAF 16/161 reads (10%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs1279057626; called by muse, mutect2, varscan2
- C7 | c.727C>T p.H243Y | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1331234989, COSV57473272; called by muse, mutect2, varscan2
- C7 | c.1193G>A p.G398E | Missense Mutation (SNP) | VAF 106/157 reads (68%) | SIFT tolerated (0.2); PolyPhen benign (0.235); catalogued as COSV57473285; called by muse, mutect2, varscan2
- C7orf31 | c.700G>C p.E234Q | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as COSV52216865; called by muse, mutect2, varscan2
- C7orf50 | c.532C>T p.P178S | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV62474286; called by muse, varscan2
- C8A | c.821C>T p.S274L | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.345); catalogued as COSV63483664, COSV63485588; called by muse, mutect2, varscan2
- C8orf33 | c.170C>T p.A57V | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs1382799720; called by mutect2, varscan2
- CA10 | c.188G>A p.G63E | Missense Mutation (SNP) | VAF 50/321 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53345322; called by muse, mutect2, varscan2
- CA2 | c.415G>A p.G139R | Missense Mutation (SNP) | VAF 61/390 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53406403, COSV53407689; called by muse, mutect2, varscan2
- CACNA2D1 | c.2369C>T p.S790L (on ENST00000356253 / NM_001366867.1; = p.S778L on NM_000722.4) | Missense Mutation (SNP) | VAF 51/109 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.288); catalogued as rs202108848, COSV62373773; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA2D4 | c.3287C>T p.S1096F | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as COSV54948279; called by muse, mutect2, varscan2
- CACNB2 | c.298G>A p.E100K (on ENST00000324631 / NM_201596.3; = p.E45K on NM_000724.4) | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1564509158, COSV56619706, COSV99030392; called by muse, mutect2, varscan2
- CACUL1 | c.994C>T p.Q332* | Nonsense Mutation (SNP) | VAF 77/181 reads (43%) | catalogued as COSV60993782; called by muse, mutect2, varscan2
- CADM3 | c.733C>T p.R245C (on ENST00000368125 / NM_001127173.3; = p.R279C on NM_021189.5) | Missense Mutation (SNP) | VAF 34/48 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1431857861, COSV63685009; called by muse, mutect2, varscan2
- CAGE1 | c.1015G>A p.E339K (on ENST00000512086; = p.E203K on NM_205864.3) | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57076454, COSV57077092, COSV57081431; called by muse, mutect2, varscan2
- CALCOCO1 | c.1699C>T p.P567S | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.207); catalogued as COSV50413167; called by muse, mutect2, varscan2
- CAMKK1 | c.1249C>G p.L417V | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV50115293; called by muse, mutect2, varscan2
- CAMLG | c.239C>T p.S80F | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV51804513; called by muse, mutect2, varscan2
- CAMTA1 | c.1652C>T p.S551F | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs1033434383, COSV57894553; called by muse, mutect2, varscan2
- CAPN11 | c.1916G>A p.W639* | Nonsense Mutation (SNP) | VAF 20/98 reads (20%) | catalogued as COSV67237115; called by muse, varscan2
- CARD11 | c.3397C>T p.R1133C | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as rs1171346123, COSV67798384; called by muse, mutect2, varscan2
- CARD11 | c.1918T>C p.F640L | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV62754899; called by muse, mutect2
- CARD11 | c.167A>T p.D56V | Missense Mutation (SNP) | VAF 32/263 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62717166; called by muse, mutect2, varscan2
- CASD1 | c.558G>A p.M186I | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV51971859; called by muse, mutect2, varscan2
- CASK | c.1780C>T p.H594Y | Missense Mutation (SNP) | VAF 27/30 reads (90%) | SIFT tolerated, low confidence (0.31); PolyPhen possibly damaging (0.478); catalogued as COSV59365016; called by muse, mutect2, varscan2
- CASR | c.84G>C p.K28N | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs1290990935, COSV56136559, COSV56142358; called by muse, mutect2, varscan2
- CASR | c.265C>T p.P89S | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV56136568; called by muse, mutect2, varscan2
- CCBE1 | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 54/125 reads (43%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.005); catalogued as COSV67949669; called by muse, mutect2, varscan2
- CCDC116 | c.519C>G p.S173R | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.394); catalogued as rs1268939280, COSV53037458; called by muse, mutect2, varscan2
- CCDC146 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV53546929; called by muse, mutect2, varscan2
- CCDC157 | c.553C>T p.Q185* | Nonsense Mutation (SNP) | VAF 32/41 reads (78%) | catalogued as COSV57838593; called by muse, mutect2, varscan2
- CCDC180 | c.4229C>T p.P1410L | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as rs757689750; called by muse, varscan2
- CCDC39 | c.884C>T p.T295M | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs1182604379, COSV56482150, COSV56483486; called by muse, mutect2, varscan2
- CCDC66 | c.1327C>T p.R443C (on ENST00000394672 / NM_001353147.1; = p.R409C on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371375228; called by muse, mutect2, varscan2
- CCNI | c.451C>T p.L151F | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.178); catalogued as COSV52959555; called by muse, mutect2, varscan2
- CCR1 | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV56121983; called by muse, mutect2, varscan2
- CCR9 | c.1046G>A p.R349K (on ENST00000357632 / NM_031200.3; = p.R337K on NM_006641.4) | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.66); PolyPhen benign (0.325); catalogued as COSV62940039; called by muse, mutect2, varscan2
- CCT5 | c.1409C>T p.P470L | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV54723567; called by muse, mutect2, varscan2
- CD101 | c.2464G>A p.E822K | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT tolerated (0.89); PolyPhen benign (0.005); catalogued as rs751950188, COSV56717156; called by muse, mutect2, varscan2
- CD163 | c.443G>A p.G148E | Missense Mutation (SNP) | VAF 68/187 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); catalogued as COSV100775839, COSV63131472; called by muse, mutect2, varscan2
- CD200R1L | c.526G>T p.E176* | Nonsense Mutation (SNP) | VAF 10/37 reads (27%) | catalogued as COSV68004080; called by muse, mutect2, varscan2
- CD207 | c.193C>T p.P65S | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.048); catalogued as rs1349977873, COSV101338608; called by muse, mutect2, varscan2
- CD2AP | c.1765C>T p.Q589* | Nonsense Mutation (SNP) | VAF 29/171 reads (17%) | catalogued as COSV63760262; called by muse, mutect2, varscan2
- CD38 | c.528G>A p.W176* | Nonsense Mutation (SNP) | VAF 24/153 reads (16%) | catalogued as COSV56889699; called by muse, mutect2, varscan2
- CD74 | c.494A>G p.N165S | Missense Mutation (SNP) | VAF 73/200 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50532499; called by muse, mutect2, varscan2
- CD8B | c.631G>A p.E211K (on ENST00000331469 / NM_172213.4; = p.E181K on NM_172102.4) | Missense Mutation (SNP) | VAF 74/224 reads (33%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.003); catalogued as rs1405194910, COSV58925651; called by muse, mutect2, varscan2
- CDC42BPB | c.2441G>A p.W814* | Nonsense Mutation (SNP) | VAF 25/49 reads (51%) | catalogued as COSV63474688; called by muse, mutect2, varscan2
- CDH1 | c.1286C>T p.P429L | Missense Mutation (SNP) | VAF 55/235 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.821); catalogued as rs876658766, COSV55730880; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDH16 | c.584G>A p.G195E | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55336121; called by muse, varscan2
- CDK11B | c.1186C>T p.P396S | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV58337826; called by muse, mutect2, varscan2
- CDK5RAP2 | c.5059C>T p.L1687F | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV62573566; called by muse, mutect2, varscan2
- CDR1 | c.58C>T p.P20S | Missense Mutation (SNP) | VAF 107/123 reads (87%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV65164093; called by muse, mutect2, varscan2
- CDS1 | c.185C>T p.P62L | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV55687560; called by muse, mutect2
- CDX1 | c.733C>T p.P245S | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51567881; called by muse, mutect2, varscan2
- CEACAM8 | c.593G>A p.R198K | Missense Mutation (SNP) | VAF 61/165 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.364); catalogued as COSV54990561; called by muse, mutect2, varscan2
- CEP112 | c.2075G>A p.R692Q | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.947); catalogued as rs1369572754, COSV67138308; called by muse, mutect2, varscan2
- CEP250 | c.664C>A p.R222S | Missense Mutation (SNP) | VAF 47/191 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.329); catalogued as rs763309863, COSV61169386; called by muse, mutect2, varscan2
- CFAP206 | c.1333G>A p.E445K | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.529); catalogued as COSV51533484; called by muse, mutect2
- CFAP54 | c.5681G>A p.R1894K | Missense Mutation (SNP) | VAF 38/142 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.324); catalogued as COSV61571727; called by muse, varscan2
- CFAP54 | c.5987G>A p.G1996E | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as rs774292976, COSV61571731; called by muse, mutect2, varscan2
- CFAP57 | c.475-1G>A p.X159_splice | Splice Site (SNP) | VAF 24/60 reads (40%) | catalogued as COSV65264207; called by muse, mutect2, varscan2
- CFAP61 | c.1136C>T p.P379L | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV55626150; called by muse, mutect2, varscan2
- CHD6 | c.4076C>T p.S1359F | Missense Mutation (SNP) | VAF 49/180 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.227); catalogued as COSV64689800; called by muse, mutect2, varscan2
- CHGB | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs1347886847; called by muse, mutect2, varscan2
- CHODL | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54732212, COSV54733494; called by muse, mutect2, varscan2
- CHRM5 | c.1508G>A p.R503K | Missense Mutation (SNP) | VAF 30/40 reads (75%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as COSV67247114; called by muse, mutect2, varscan2
- CHRNB3 | c.459C>A p.C153* | Nonsense Mutation (SNP) | VAF 15/39 reads (38%) | catalogued as COSV51494462; called by muse, mutect2, varscan2
- CIB4 | c.399T>G p.D133E | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV56600203; called by muse, mutect2, varscan2
- CILK1 | c.1916G>A p.R639Q (on ENST00000350082 / NM_001375397.1; = p.R632Q on NM_014920.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/209 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs893035689, COSV63153936; called by muse, mutect2, varscan2
- CILK1 | c.1640C>T p.S547L (on ENST00000350082 / NM_001375397.1; = p.S540L on NM_014920.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/189 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as COSV63153942; called by muse, mutect2, varscan2
- CKAP5 | c.3874C>T p.P1292S | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56366441; called by muse, mutect2, varscan2
- CLEC11A | c.71G>A p.G24E | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.005); catalogued as COSV51573759; called by muse, mutect2, varscan2
- CLPS | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 32/204 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.258); catalogued as rs751569641, COSV52566154; called by muse, mutect2, varscan2
- CLU | c.742C>T p.L248F | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV57066362; called by muse, mutect2, varscan2
- CNGA3 | c.2047C>T p.P683S | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV55623733; called by muse, mutect2, varscan2
- CNGB3 | c.2131G>A p.E711K | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.72); PolyPhen benign (0.017); catalogued as rs1184824947, COSV60688088; called by muse, mutect2, varscan2
- CNOT6L | c.509C>T p.P170L (on ENST00000504123 / NM_001286790.2; = p.P165L on NM_144571.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53698729; called by muse, mutect2, varscan2
- CNTN3 | c.2991G>A p.M997I | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV55168233; called by muse, mutect2, varscan2
- CNTN4 | c.386G>A p.R129K | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV68569063; called by muse, mutect2, varscan2
- COBL | c.3740C>T p.S1247F | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54343191; called by muse, mutect2, varscan2
- COL11A1 | c.4982C>T p.S1661L | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.393); catalogued as COSV62180146; called by mutect2, varscan2
- COL11A2 | c.643C>T p.Q215* | Nonsense Mutation (SNP) | VAF 30/376 reads (8%) | catalogued as COSV59495804; called by muse, mutect2
- COL14A1 | c.2102G>A p.S701N | Missense Mutation (SNP) | VAF 27/197 reads (14%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.519); catalogued as COSV52852011; called by muse, mutect2, varscan2
- COL14A1 | c.5323G>A p.D1775N | Missense Mutation (SNP) | VAF 37/282 reads (13%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.69); catalogued as COSV52852022; called by muse, mutect2, varscan2
- COL16A1 | c.3257C>T p.P1086L | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV54704010; called by muse, mutect2, varscan2
- COL1A1 | c.2294T>C p.L765P | Missense Mutation (SNP) | VAF 33/48 reads (69%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.904); catalogued as COSV56803822; called by muse, mutect2, varscan2
- COL1A2 | c.2363T>G p.F788C | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51956317; called by muse, mutect2, varscan2
- COL22A1 | c.3224G>A p.G1075D | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57332510; called by muse, mutect2, varscan2
- COL23A1 | c.838-2A>C p.X280_splice | Splice Site (SNP) | VAF 17/37 reads (46%) | catalogued as COSV66789333; called by muse, mutect2, varscan2
- COL25A1 | c.1581C>T p.I527= | Splice Region (SNP) | VAF 29/67 reads (43%) | catalogued as COSV67649111; called by muse, mutect2, varscan2
- COL28A1 | c.2129G>A p.G710E | Missense Mutation (SNP) | VAF 18/228 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68081648; called by muse, mutect2
- COL28A1 | c.1909G>A p.D637N | Missense Mutation (SNP) | VAF 19/355 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV68081653; called by muse, mutect2
- COL28A1 | c.1709C>T p.P570L | Missense Mutation (SNP) | VAF 30/190 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.456); catalogued as COSV68081657; called by muse, mutect2, varscan2
- COL2A1 | c.4411G>A p.G1471R | Missense Mutation (SNP) | VAF 40/137 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56742634; called by muse, mutect2, varscan2
- COL2A1 | c.1267-1G>A p.X423_splice | Splice Site (SNP) | VAF 25/82 reads (30%) | catalogued as COSV100477279, COSV61529656; called by muse, mutect2, varscan2
- COL3A1 | c.3981G>A p.W1327* | Nonsense Mutation (SNP) | VAF 34/64 reads (53%) | catalogued as COSV58585662; called by muse, varscan2
- COL4A4 | c.2500G>A p.G834R | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61631255, COSV61633948; called by muse, mutect2, varscan2
- COL6A1 | c.1763C>T p.P588L | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.45); catalogued as rs759442615, CM1310883, COSV62612654; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A2 | c.2536G>A p.E846K | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.756); catalogued as rs772005975, COSV52424673; ClinVar: uncertain significance; called by muse, mutect2
- COL6A3 | c.736C>T p.L246F | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55086390; called by muse, mutect2, varscan2
- COLEC10 | c.185G>A p.G62E | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60521034, COSV60522022; called by muse, mutect2, varscan2
- CPNE9 | c.1558G>A p.E520K | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780878680, COSV56068173; called by muse, mutect2, varscan2
- CPT1A | c.2020C>T p.L674F | Missense Mutation (SNP) | VAF 101/148 reads (68%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV55752848, COSV55755069; called by muse, mutect2, varscan2
- CPT1C | c.282-1G>A p.X94_splice | Splice Site (SNP) | VAF 43/87 reads (49%) | catalogued as COSV54918660; called by muse, mutect2, varscan2
- CR1 | c.5108C>T p.A1703V | Missense Mutation (SNP) | VAF 39/187 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.355); catalogued as rs759251578, COSV65457488; called by muse, mutect2, varscan2
- CRABP2 | c.175G>C p.V59L | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as COSV63958854; called by muse, mutect2, varscan2
- CRB1 | c.2885T>C p.L962S | Missense Mutation (SNP) | VAF 43/138 reads (31%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.543); catalogued as COSV66329524; called by muse, mutect2, varscan2
- CRNN | c.1436G>A p.R479Q | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs138795800, COSV55121876; called by muse, mutect2, varscan2
- CRTAC1 | c.157C>T p.Q53* | Nonsense Mutation (SNP) | VAF 33/82 reads (40%) | catalogued as COSV54000402, COSV54008226; called by muse, mutect2, varscan2
- CRY1 | c.1408A>T p.M470L | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.088); catalogued as COSV50481820; called by muse, varscan2
- CRY1 | c.1373C>T p.A458V | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.6); catalogued as COSV50481842; called by muse, varscan2
- CRYBA4 | c.358G>A p.G120R | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.117); catalogued as COSV61321804; called by muse, varscan2
- CRYM | c.875C>T p.S292F | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54830594; called by muse, mutect2, varscan2
- CSMD1 | c.4295G>C p.C1432S (on ENST00000520002; = p.C1431S on NM_033225.6) | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV59308733; called by muse, mutect2, varscan2
- CSMD3 | c.6255G>A p.Q2085= (on ENST00000297405 / NM_001363185.1; = p.Q1981= on NM_052900.3) | Splice Region (SNP) | VAF 17/117 reads (15%) | catalogued as COSV52153836, COSV52213903; called by muse, mutect2, varscan2
- CSMD3 | c.3717T>G p.A1239= (on ENST00000297405 / NM_001363185.1; = p.A1135= on NM_052900.3) | Splice Region (SNP) | VAF 15/129 reads (12%) | catalogued as COSV52153857; called by muse, mutect2, varscan2
- CSNK1A1L | c.298C>T p.L100F | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV65789559; called by muse, mutect2, varscan2
- CST9L | c.58G>A p.G20S | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.708); catalogued as rs749707803, COSV65407786, COSV65408423; called by muse, mutect2, varscan2
- CTNND2 | c.3625G>A p.E1209K | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.952); catalogued as COSV58861580; called by muse, mutect2, varscan2
- CWH43 | c.1189C>T p.L397= | Splice Region (SNP) | VAF 35/130 reads (27%) | catalogued as COSV56937971; called by muse, mutect2, varscan2
- CXCR1 | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as COSV55281636; called by muse, mutect2, varscan2
- CXXC1 | c.82T>C p.Y28H | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53274028; called by muse, mutect2, varscan2
- CXorf21 | c.433C>T p.P145S | Missense Mutation (SNP) | VAF 23/27 reads (85%) | SIFT tolerated (0.52); PolyPhen benign (0.053); catalogued as COSV66762639; called by muse, mutect2, varscan2
- CXorf58 | c.817C>T p.R273W | Missense Mutation (SNP) | VAF 56/59 reads (95%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.855); catalogued as rs369841797, COSV64858091; called by muse, mutect2, varscan2
- CYP11B2 | c.1256G>A p.R419K | Missense Mutation (SNP) | VAF 28/167 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as COSV59995541, COSV59997093; called by muse, mutect2, varscan2
- CYP11B2 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 38/129 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.255); catalogued as COSV100010711; called by muse, mutect2, varscan2
- CYP17A1 | c.199C>T p.R67C | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.978); catalogued as rs750853745, COSV64004858; called by muse, mutect2, varscan2
- CYP27B1 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV56984564, COSV56986718; called by muse, mutect2, varscan2
- CYP2A6 | c.1244A>C p.H415P | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56534818; called by muse, mutect2, varscan2
- CYP3A5 | c.1254-1G>A p.X418_splice | Splice Site (SNP) | VAF 34/92 reads (37%) | catalogued as COSV56119450; called by muse, mutect2, varscan2
- CYP3A7-CYP3A51P | c.1510G>A p.E504K | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.068); catalogued as rs1477957460; called by muse, mutect2
- CYP7A1 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 44/290 reads (15%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.607); catalogued as COSV56963160; called by muse, mutect2, varscan2
- CYTH3 | c.730A>T p.K244* | Nonsense Mutation (SNP) | VAF 10/120 reads (8%) | catalogued as COSV63438351; called by muse, mutect2
- DBX2 | c.853C>A p.Q285K | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.057); catalogued as rs1188471924, COSV60337218; called by muse, mutect2, varscan2
- DCAF11 | c.1093-1G>A p.X365_splice | Splice Site (SNP) | VAF 60/148 reads (41%) | catalogued as COSV58108838; called by muse, mutect2, varscan2
- DCAF4 | c.872C>T p.S291F | Missense Mutation (SNP) | VAF 74/185 reads (40%) | SIFT tolerated (0.49); PolyPhen benign (0.223); catalogued as COSV62319391; called by muse, mutect2, varscan2
- DCAF8L1 | c.329A>T p.E110V | Missense Mutation (SNP) | VAF 20/23 reads (87%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as COSV71595223; called by muse, mutect2, varscan2
- DDHD1 | c.912+1G>A p.X304_splice (on ENST00000323669; = p.X501_splice on NM_030637.3) | Splice Site (SNP) | VAF 13/36 reads (36%) | catalogued as COSV60358604; called by muse, mutect2
- DDI1 | c.247C>T p.R83W | Missense Mutation (SNP) | VAF 52/136 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV56374584; called by muse, mutect2, varscan2
- DDX3X | c.1232C>T p.S411F (on ENST00000399959; = p.S412F on NM_001356.5) | Missense Mutation (SNP) | VAF 26/31 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV67863397; called by muse, mutect2, varscan2
- DDX60 | c.2255G>A p.R752K | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV67096290; called by muse, mutect2, varscan2
- DEFB115 | c.32G>A p.G11E | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.795); catalogued as COSV68723031, COSV68723070; called by muse, mutect2, varscan2
- DEFB125 | c.275C>T p.P92L | Missense Mutation (SNP) | VAF 28/173 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as rs1301113646, COSV66703228; called by muse, mutect2, varscan2
- DEFB136 | c.232C>T p.H78Y | Missense Mutation (SNP) | VAF 53/243 reads (22%) | PolyPhen benign (0.132); catalogued as COSV66363831; called by muse, mutect2, varscan2
- DENND1C | c.1819G>A p.D607N | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.025); catalogued as rs771078919, COSV57568382; called by muse, mutect2, varscan2
- DENND4C | c.3008T>G p.V1003G (on ENST00000434457 / NM_001330640.2; = p.V954G on NM_017925.7) | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV63008647; called by muse, mutect2, varscan2
- DENND5A | c.3470C>T p.S1157L | Missense Mutation (SNP) | VAF 56/121 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as rs777434155, COSV60232996; called by muse, mutect2, varscan2
- DEPDC5 | c.1514C>T p.S505F | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.59); catalogued as COSV56695221; called by muse, mutect2, varscan2
- DES | c.875C>T p.A292V | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV64660204; called by muse, mutect2, varscan2
- DGAT2 | c.427C>T p.Q143* | Nonsense Mutation (SNP) | VAF 20/88 reads (23%) | catalogued as COSV57175960; called by muse, mutect2, varscan2
- DGAT2 | c.867C>G p.I289M | Missense Mutation (SNP) | VAF 45/206 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.69); catalogued as rs976388037, COSV57175970; called by muse, mutect2, varscan2
- DGKD | c.1379C>T p.S460F (on ENST00000264057 / NM_152879.3; = p.S416F on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.535); catalogued as rs375904433; called by muse, mutect2, varscan2
- DHX34 | c.3212A>C p.H1071P | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.133); catalogued as rs1486965793; called by muse, mutect2, varscan2
- DICER1 | c.3425C>T p.S1142F | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.024); catalogued as rs1212563071, COSV58616378; called by muse, mutect2, varscan2
- DISP3 | c.665G>A p.R222Q | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs779679457, COSV53820570; called by mutect2, varscan2
- DKK1 | c.152G>A p.G51D | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV64760156; called by muse, mutect2, varscan2
- DKK3 | c.314G>A p.G105E | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.142); catalogued as COSV58867834, COSV58868276; called by muse, mutect2, varscan2
- DLGAP3 | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52395504; called by muse, mutect2, varscan2
- DMBT1 | c.2395G>A p.D799N | Missense Mutation (SNP) | VAF 49/107 reads (46%) | SIFT tolerated (0.39); PolyPhen benign (0.024); catalogued as COSV57539111; called by muse, mutect2, varscan2
- DNAAF3 | c.1235C>T p.A412V (on ENST00000524407 / NM_001256715.2; = p.A459V on NM_178837.4) | Missense Mutation (SNP) | VAF 46/178 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.461); catalogued as COSV61276449; called by muse, varscan2
- DNAH10 | c.2156G>A p.R719K (on ENST00000409039; = p.R658K on NM_207437.3) | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101292960; called by muse, mutect2, varscan2
- DNAH10 | c.3310G>A p.D1104N (on ENST00000409039; = p.D1043N on NM_207437.3) | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.761); catalogued as COSV68991652; called by muse, mutect2, varscan2
- DNAH10 | c.8995G>A p.D2999N (on ENST00000409039; = p.D2938N on NM_207437.3) | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.098); catalogued as COSV68991661; called by muse, mutect2, varscan2
- DNAH11 | c.4223G>A p.R1408K | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.652); catalogued as COSV60951564; called by muse, mutect2, varscan2
- DNAH12 | c.595C>T p.Q199* | Nonsense Mutation (SNP) | VAF 20/52 reads (38%) | catalogued as COSV60856487; called by muse, mutect2, varscan2
- DNAH17 | c.4339G>A p.E1447K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1359501567, COSV67752379; called by muse, mutect2
- DNAH3 | c.3794G>A p.G1265E | Missense Mutation (SNP) | VAF 50/132 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV54515688; called by muse, mutect2, varscan2
- DNAH7 | c.11696C>T p.P3899L | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56758876, COSV56760008; called by muse, mutect2, varscan2
- DNAH7 | c.4345C>T p.R1449W | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764307923, COSV100414457; called by muse, mutect2, varscan2
- DNAH8 | c.6652G>A p.V2218I | Missense Mutation (SNP) | VAF 31/180 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs749048233, COSV59438407; called by muse, mutect2, varscan2
- DNAJA2 | c.444C>T p.G148= | Splice Region (SNP) | VAF 46/92 reads (50%) | catalogued as rs1329562193, COSV57694635; called by muse, mutect2, varscan2
- DNAJC5 | c.127C>T p.H43Y | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62671353; called by muse, mutect2
- DNASE1 | c.211G>A p.G71R | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0.106); catalogued as rs942594189, COSV55913112; called by muse, mutect2, varscan2
- DNASE1L3 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1320165388, COSV59155316; called by muse, mutect2, varscan2
- DNM3 | c.2258C>T p.P753L (on ENST00000355305 / NM_001350206.2; = p.P747L on NM_015569.5) | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs777632501, COSV62456380; called by muse, varscan2
- DNMT3L | c.45G>A p.M15I | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs1445379144, COSV54263736; called by muse, varscan2
- DOCK3 | c.3099G>A p.W1033* | Nonsense Mutation (SNP) | VAF 21/69 reads (30%) | catalogued as COSV56515164; called by muse, mutect2, varscan2
- DOCK3 | c.4819G>A p.E1607K | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.752); catalogued as rs1393396688, COSV56515186; called by muse, mutect2, varscan2
- DOCK7 | c.3874G>C p.A1292P (on ENST00000635253 / NM_001367561.1; = p.A1261P on NM_033407.3) | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52002308; called by muse, mutect2, varscan2
- DOK6 | c.647G>A p.G216E | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66929320; called by muse, mutect2, varscan2
- DONSON | c.471G>C p.W157C | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51676991; called by muse, mutect2
- DPY19L4 | c.904C>T p.L302F | Missense Mutation (SNP) | VAF 159/863 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as rs768790617, COSV68962647; called by muse, mutect2, varscan2
- DPYD | c.1634C>T p.P545L | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64595000; called by muse, mutect2, varscan2
- DSC1 | c.1539T>G p.D513E | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV57144268; called by muse, mutect2, varscan2
- DSC3 | c.1114G>A p.E372K | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.213); catalogued as COSV64571434; called by muse, mutect2, varscan2
- DSC3 | c.421C>A p.P141T | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV64572599, COSV64575131; called by muse, mutect2, varscan2
- DSG3 | c.1519C>T p.P507S | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.063); catalogued as rs561268376; called by muse, mutect2, varscan2
- DSG3 | c.2231G>A p.G744E | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV57125517; called by muse, mutect2, varscan2
- DSG3 | c.2455G>A p.E819K | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57125525; called by muse, mutect2, varscan2
- DSP | c.3209C>T p.S1070F | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV65791478; called by muse, mutect2, varscan2
- DSP | c.3964G>A p.D1322N | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.202); catalogued as COSV65792280; called by muse, mutect2, varscan2
- DSP | c.4678C>T p.Q1560* | Nonsense Mutation (SNP) | VAF 30/191 reads (16%) | catalogued as COSV65792281; called by muse, mutect2, varscan2
- DSP | c.7241G>T p.G2414V | Missense Mutation (SNP) | VAF 37/181 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65790969, COSV65792284; called by muse, mutect2, varscan2
- DSP | c.7720G>C p.G2574R | Missense Mutation (SNP) | VAF 21/173 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.052); catalogued as rs1006882435, COSV65792287, COSV99059801; called by muse, mutect2, varscan2
- DTNA | c.2089G>A p.E697K | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.178); catalogued as COSV51999171; called by muse, mutect2, varscan2
- DTX4 | c.1522C>T p.P508S | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.996); catalogued as rs1231983287, COSV57089750, COSV57093823; called by muse, mutect2, varscan2
- DUOX2 | c.2735G>A p.G912E | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV66531557; called by muse, mutect2, varscan2
- DUSP26 | c.205C>T p.L69F | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV56361193; called by muse, mutect2, varscan2
- DYNC1I2 | c.302G>A p.S101N | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.995); catalogued as COSV55525381; called by muse, mutect2, varscan2
- E4F1 | c.1390G>C p.A464P | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV100065334, COSV57038558; called by muse, mutect2, varscan2
- EBF3 | c.227A>G p.D76G | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV62473922; called by muse, mutect2, varscan2
- ECEL1 | c.446C>T p.T149I | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as COSV58811846; called by muse, mutect2, varscan2
- EDEM2 | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV65712842; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.968G>A p.W323* | Nonsense Mutation (SNP) | VAF 12/73 reads (16%) | catalogued as rs1288968597, COSV62567345; called by muse, mutect2, varscan2
- EFCAB5 | c.1970G>A p.G657E | Missense Mutation (SNP) | VAF 45/70 reads (64%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV57928331; called by muse, mutect2, varscan2
- EFCAB6 | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs774551472, COSV53061506; called by muse, mutect2, varscan2
- EFHB | c.1237G>A p.G413R | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV55547019; called by muse, mutect2, varscan2
- EGFR | c.1621C>T p.L541F | Missense Mutation (SNP) | VAF 49/181 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1208487495, COSV51790737, COSV51841184; called by muse, mutect2, varscan2
- EIF4G2 | c.883C>T p.R295C | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60596814; called by muse, mutect2, varscan2
- ELAPOR2 | c.2701T>G p.W901G (on ENST00000450689 / NM_001142749.3; = p.W734G on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51885728, COSV99788853; called by muse, mutect2, varscan2
- ELOA | c.1673C>T p.S558F | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV69309932, COSV69311452; called by muse, mutect2, varscan2
- ELOA2 | c.1798G>A p.E600K | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV55295225; called by muse, mutect2, varscan2
- ELOA2 | c.1621C>T p.P541S | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as rs1427162391; called by muse, mutect2, varscan2
- ELOA2 | c.1090C>T p.L364F | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT tolerated (0.83); PolyPhen benign (0.143); catalogued as COSV55297247; called by muse, mutect2, varscan2
- EML4 | c.1943T>G p.V648G | Missense Mutation (SNP) | VAF 62/116 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV59296346; called by muse, mutect2, varscan2
- EML5 | c.3266G>A p.R1089Q | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as rs773359380, COSV61344362; called by muse, mutect2, varscan2
- ENPP7 | c.175C>T p.R59* | Nonsense Mutation (SNP) | VAF 16/45 reads (36%) | catalogued as rs199868387; called by muse, mutect2, varscan2
- ENTPD1 | c.349C>T p.P117S | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64601146; called by muse, mutect2, varscan2
- EP300 | c.5630C>T p.P1877L | Missense Mutation (SNP) | VAF 17/158 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.407); catalogued as COSV54330763; called by muse, mutect2
- EPHA10 | c.3014G>A p.G1005E | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV57623420; called by muse, mutect2, varscan2
- EPHA2 | c.2116G>A p.E706K | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1170410561, COSV64452779; called by muse, varscan2
- EPHA3 | c.1915C>T p.R639C | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); catalogued as rs754102338, COSV60701442, COSV60729089; called by muse, mutect2, varscan2
- EPHB1 | c.634G>A p.G212R | Missense Mutation (SNP) | VAF 72/238 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV67658514; called by muse, mutect2, varscan2
- EPPK1 | c.5620C>T p.R1874C | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs372213876; called by muse, mutect2
- ERBB4 | c.2276C>T p.P759L | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.275); catalogued as COSV53522339; called by muse, mutect2, varscan2
- ERICH3 | c.4430G>A p.G1477E | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as rs542267741, COSV58604371; called by muse, mutect2, varscan2
- ERO1B | c.1216G>A p.G406S | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51595524; called by muse, mutect2, varscan2
- ERVW-1 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.268); catalogued as COSV71259383; called by muse, mutect2, varscan2
- ESRP1 | c.1126C>T p.L376F | Missense Mutation (SNP) | VAF 194/947 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64409014; called by muse, mutect2, varscan2
- EVC | c.2500C>T p.P834S | Missense Mutation (SNP) | VAF 28/195 reads (14%) | SIFT tolerated (0.72); PolyPhen benign (0.018); catalogued as rs1395596111, COSV53829401, COSV53831513; called by muse, mutect2, varscan2
- EVPL | c.1223G>A p.R408Q | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767324618, COSV56908538; called by mutect2, varscan2
- EXOC6B | c.889C>T p.R297* | Nonsense Mutation (SNP) | VAF 7/42 reads (17%) | catalogued as rs749876156, COSV55550273; called by mutect2, varscan2
- EZHIP | c.121C>T p.P41S | Missense Mutation (SNP) | VAF 12/12 reads (100%) | SIFT tolerated (0.09); PolyPhen benign (0.318); catalogued as rs1557318586, COSV100539671; called by muse, mutect2, varscan2
- FA2H | c.714C>G p.F238L | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); catalogued as rs1286114110; called by muse, mutect2, varscan2
- FAM117B | c.1210A>C p.S404R | Missense Mutation (SNP) | VAF 135/347 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV57418318; called by muse, mutect2, varscan2
- FAM135B | c.2202A>C p.E734D | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.04); catalogued as COSV52717950; called by muse, mutect2
- FAM161A | c.701C>T p.P234L | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56765380; called by muse, mutect2, varscan2
- FAM221B | c.544G>A p.G182R | Missense Mutation (SNP) | VAF 42/173 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as COSV65074211; called by muse, mutect2, varscan2
- FAM83A | c.363G>A p.W121* | Nonsense Mutation (SNP) | VAF 31/163 reads (19%) | catalogued as rs1252052815, COSV52684942; called by muse, mutect2, varscan2
- FAM83B | c.2608C>T p.P870S | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as COSV100174429, COSV60921237; called by muse, mutect2, varscan2
- FAM98C | c.940G>A p.D314N | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV53038600; called by muse, mutect2, varscan2
- FAT2 | c.1646C>T p.S549F | Missense Mutation (SNP) | VAF 26/162 reads (16%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.755); catalogued as COSV55817661; called by muse, mutect2, varscan2
- FAT4 | c.9143C>T p.S3048F | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); catalogued as COSV58679827; called by muse, mutect2, varscan2
- FAT4 | c.9487G>A p.E3163K | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.993); catalogued as rs370088878, CM1311052; called by muse, mutect2, varscan2
- FAT4 | c.10879G>A p.G3627S | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.067); catalogued as COSV58679853; called by muse, mutect2, varscan2
- FBN1 | c.5393T>G p.F1798C | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as COSV57314377; called by muse, mutect2, varscan2
- FBN2 | c.5704G>A p.V1902I | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0.047); catalogued as rs764783994, COSV52507110, COSV52553667; called by mutect2, varscan2
- FBXL6 | c.1349A>C p.Q450P | Missense Mutation (SNP) | VAF 72/214 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV57351569; called by muse, mutect2, varscan2
- FBXO3 | c.335C>T p.P112L | Missense Mutation (SNP) | VAF 40/202 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); catalogued as COSV55765843; called by muse, mutect2, varscan2
- FBXO42 | c.1787G>A p.G596E | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.01); catalogued as COSV65045340; called by muse, mutect2, varscan2
- FBXO46 | c.281C>T p.P94L | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV58348347; called by muse, mutect2, varscan2
- FCHO1 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53182019; called by muse, mutect2, varscan2
- FCRL3 | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 70/97 reads (72%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.643); catalogued as COSV100942808, COSV63840826; called by muse, varscan2
- FGD5 | c.3316G>A p.D1106N | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.011); catalogued as rs1303571738, COSV53240759; called by muse, mutect2, varscan2
- FGD5 | c.3905A>C p.K1302T | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as COSV53240777; called by muse, mutect2, varscan2
- FGF12 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); catalogued as COSV53160520; called by muse, varscan2
- FHOD1 | c.16G>A p.D6N | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs1214633722, COSV50759919, COSV50764276; called by muse, mutect2, varscan2
- FIG4 | c.2455T>C p.S819P | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as COSV57786878; called by muse, mutect2, varscan2
- FILIP1 | c.2963G>A p.R988K | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV52727216; called by muse, mutect2, varscan2
- FLG2 | c.5546G>A p.G1849E | Missense Mutation (SNP) | VAF 56/243 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.017); catalogued as COSV66167944; called by muse, mutect2, varscan2
- FLG2 | c.5390G>A p.G1797E | Missense Mutation (SNP) | VAF 56/252 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.559); catalogued as COSV66167949; called by muse, mutect2, varscan2
- FLNB | c.1975G>A p.G659R | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55876451; called by muse, mutect2, varscan2
- FLRT2 | c.722C>T p.S241L | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as rs755733449, COSV58137055; called by muse, mutect2, varscan2
- FLRT3 | c.1729G>A p.E577K | Missense Mutation (SNP) | VAF 41/182 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53971194; called by muse, mutect2, varscan2
- FLVCR2 | c.1265G>A p.G422E | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV53161914; called by muse, mutect2, varscan2
- FNDC7 | c.1115C>T p.P372L | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54752432; called by muse, mutect2, varscan2
- FOLH1 | c.2179G>C p.E727Q | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.471); catalogued as COSV57047085, COSV57048031; called by muse, mutect2, varscan2
- FOXP4 | c.1399C>T p.R467W (on ENST00000307972 / NM_001012426.1; = p.R454W on NM_138457.3) | Missense Mutation (SNP) | VAF 25/208 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57219469; called by muse, varscan2
- FPR1 | c.731C>T p.S244F | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.652); catalogued as rs755314613, COSV59051681; called by muse, mutect2, varscan2
- FREM1 | c.5450G>A p.G1817E | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.544); catalogued as COSV66521825; called by muse, mutect2, varscan2
- FREM1 | c.3674C>T p.S1225F | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV66521838; called by muse, mutect2, varscan2
- FREM2 | c.6818G>C p.R2273T | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV54834672; called by muse, mutect2, varscan2
- FRMPD1 | c.2728G>A p.E910K | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV66700028; called by muse, mutect2, varscan2
- GABPB2 | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.193); catalogued as COSV64460704; called by muse, mutect2, varscan2
- GABRB2 | c.1228G>A p.E410K (on ENST00000274547; = p.E372K on NM_000813.3) | Missense Mutation (SNP) | VAF 48/133 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.089); catalogued as rs148772321, COSV99196631; called by muse, mutect2, varscan2
- GABRG2 | c.1468C>T p.P490S (on ENST00000361925 / NM_001375343.1; = p.P450S on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 109/288 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62717080; called by muse, mutect2, varscan2
- GABRR1 | c.223T>A p.S75T | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated (0.59); PolyPhen benign (0.05); catalogued as COSV65619196; called by muse, mutect2, varscan2
- GALNT15 | c.1153C>T p.L385F | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.593); catalogued as COSV60216495; called by muse, mutect2, varscan2
- GAS2L1 | c.1862C>T p.P621L | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV53330293; called by muse, mutect2, varscan2
- GATA2 | c.814G>A p.G272R | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs367955980; called by muse, varscan2
- GBF1 | c.260C>T p.T87I | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV64144243; called by muse, mutect2, varscan2
- GBP5 | c.1102A>T p.K368* | Nonsense Mutation (SNP) | VAF 35/67 reads (52%) | catalogued as COSV58592304, COSV58593821; called by muse, mutect2, varscan2
- GCM2 | c.1094C>T p.P365L | Missense Mutation (SNP) | VAF 51/349 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65275401; called by muse, mutect2, varscan2
- GCNT3 | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.048); catalogued as rs771411777, COSV68532150; called by muse, mutect2, varscan2
- GIGYF2 | c.3862C>T p.L1288F | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV65248383; called by muse, mutect2, varscan2
- GIMAP6 | c.170G>A p.G57E | Missense Mutation (SNP) | VAF 110/255 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61032754; called by muse, mutect2, varscan2
- GIT2 | c.56C>T p.P19L | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.848); catalogued as COSV58080057; called by muse, mutect2, varscan2
- GLB1 | c.1967C>T p.P656L | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.117); catalogued as rs1356418704; called by muse, mutect2, varscan2
- GLB1 | c.1966C>T p.P656S | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV56563106; called by muse, mutect2, varscan2
- GLI1 | c.1133C>T p.S378L | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs774005775, COSV57360674; called by mutect2, varscan2
- GLI2 | c.287C>T p.S96F | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58039477; called by muse, mutect2, varscan2
- GLI2 | c.1339C>T p.H447Y (on ENST00000361492 / NM_001374353.1; = p.H464Y on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/135 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV58039487; called by muse, mutect2, varscan2
- GLRX3 | c.256C>T p.P86S | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58692214; called by muse, mutect2, varscan2
- GMEB1 | c.1687G>A p.V563I | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.191); catalogued as rs1381625900, COSV53793996; called by muse, mutect2, varscan2
- GOLGB1 | c.3329T>A p.L1110* | Nonsense Mutation (SNP) | VAF 38/126 reads (30%) | catalogued as COSV61464280; called by muse, mutect2, varscan2
- GON4L | c.514C>G p.Q172E | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as COSV55191575; called by muse, mutect2, varscan2
- GPATCH1 | c.2266G>A p.A756T | Missense Mutation (SNP) | VAF 33/366 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs928702192, COSV50113218; called by muse, mutect2
- GPI | c.479C>T p.S160F | Missense Mutation (SNP) | VAF 36/140 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV62893811; called by muse, mutect2, varscan2
- GPR1 | c.155G>A p.G52E | Missense Mutation (SNP) | VAF 72/147 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67976701; called by muse, mutect2, varscan2
- GPR149 | c.1732G>A p.E578K | Missense Mutation (SNP) | VAF 58/185 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as COSV67666867; called by muse, mutect2, varscan2
- GPR15 | c.826C>T p.P276S | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1163266619, COSV52520395; called by muse, mutect2, varscan2
- GPR152 | c.293C>T p.P98L | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs755426722; called by muse, mutect2, varscan2
- GPR161 | c.767T>A p.F256Y | Missense Mutation (SNP) | VAF 52/235 reads (22%) | SIFT tolerated (0.83); PolyPhen benign (0.138); catalogued as COSV54789362; called by muse, mutect2, varscan2
- GPR174 | c.618G>A p.W206* | Nonsense Mutation (SNP) | VAF 29/32 reads (91%) | catalogued as COSV52132055; called by muse, mutect2, varscan2
- GPR179 | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 39/62 reads (63%) | SIFT deleterious (0.02); PolyPhen benign (0.149); catalogued as rs757517702; called by muse, mutect2, varscan2
- GPR31 | c.944G>A p.R315K | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs761637610, COSV64761324, COSV64761930; called by muse, mutect2, varscan2
- GPR61 | c.19C>T p.P7S | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV68177896; called by muse, mutect2, varscan2
- GPR85 | c.345C>G p.I115M | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); catalogued as COSV51783217; called by muse, mutect2, varscan2
- GPRIN3 | c.151C>T p.P51S | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.226); catalogued as rs1288631894, COSV60884627; called by muse, mutect2, varscan2
- GPX5 | c.475C>T p.P159S | Missense Mutation (SNP) | VAF 65/395 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.04); catalogued as rs868415334, COSV69079299; called by muse, mutect2, varscan2
- GPX6 | c.566G>A p.G189E | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62657279; called by muse, mutect2, varscan2
- GRIK3 | c.1802C>T p.S601F | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV66138266; called by muse, mutect2, varscan2
- GRIK4 | c.1012G>A p.A338T | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.62); PolyPhen benign (0.121); catalogued as rs1030398477, COSV70802571; called by mutect2, varscan2
- GRIN2A | c.2746G>A p.D916N | Missense Mutation (SNP) | VAF 60/155 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58028762; called by muse, mutect2, varscan2
- GRM7 | c.1088G>A p.W363* | Nonsense Mutation (SNP) | VAF 12/36 reads (33%) | catalogued as COSV63139185; called by muse, mutect2, varscan2
- GSDMC | c.699T>G p.D233E | Missense Mutation (SNP) | VAF 56/153 reads (37%) | SIFT tolerated (0.52); PolyPhen benign (0.056); catalogued as COSV52694774; called by muse, mutect2, varscan2
- GSE1 | c.1741C>G p.P581A | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.878); catalogued as COSV53671240; called by muse, mutect2
- GSS | c.866C>T p.S289L | Missense Mutation (SNP) | VAF 35/174 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53624142; called by muse, mutect2, varscan2
- GUCY1B1 | c.1678G>A p.G560R | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1327101928, COSV52374959; called by muse, mutect2, varscan2
- GYS2 | c.1448C>T p.S483F | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV53922336; called by muse, mutect2, varscan2
- H1-6 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1196722235, COSV58090317; called by muse, mutect2, varscan2
- H2AC1 | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.02); catalogued as rs1418751341, COSV51237093, COSV99219604; called by muse, mutect2, varscan2
- H2AZ2 | c.83T>A p.F28Y | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56062258; called by muse, mutect2, varscan2
- H4C11 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as COSV100748035; called by mutect2, varscan2
- H4C9 | c.170G>A p.G57E | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.793); catalogued as rs140361782; called by muse, mutect2, varscan2
- HARBI1 | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.289); catalogued as rs141436294; called by muse, mutect2, varscan2
- HCAR2 | c.905C>T p.P302L | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as COSV61024728; called by muse, mutect2, varscan2
- HDAC7 | c.404C>T p.P135L (on ENST00000427332; = p.P174L on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.264); catalogued as COSV50338753; called by muse, mutect2, varscan2
- HEATR1 | c.2419C>T p.P807S | Missense Mutation (SNP) | VAF 62/95 reads (65%) | SIFT tolerated (0.69); PolyPhen benign (0.015); catalogued as rs1277198658, COSV63980681; called by muse, mutect2, varscan2
- HELZ | c.5450C>T p.P1817L | Missense Mutation (SNP) | VAF 39/151 reads (26%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.46); catalogued as rs771350648, COSV62377635, COSV62378753; called by muse, varscan2
- HERC6 | c.458G>A p.G153E | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52029204; called by muse, mutect2, varscan2
- HGFAC | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.55); PolyPhen benign (0.012); catalogued as rs748242367, COSV58750672; called by muse, mutect2, varscan2
- HLF | c.71C>T p.S24F | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV56829556; called by muse, mutect2, varscan2
- HLX | c.1052C>T p.P351L | Missense Mutation (SNP) | VAF 50/76 reads (66%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV65044660; called by muse, mutect2, varscan2
- HMGXB4 | c.1135C>T p.P379S | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.037); catalogued as rs28522155, COSV53333562; called by muse, mutect2, varscan2
- HNRNPA1L2 | c.619G>A p.G207R | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.038); catalogued as COSV61255193; called by muse, mutect2, varscan2
- HOXB13 | c.664C>T p.P222S | Missense Mutation (SNP) | VAF 47/79 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51704482; called by muse, mutect2, varscan2
- HOXC8 | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50000970, COSV99236630; called by muse, mutect2, varscan2
- HPCAL4 | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as COSV65716188; called by mutect2, varscan2
- HSD17B4 | c.1483G>A p.G495S (on ENST00000414835 / NM_001199291.3; = p.G470S on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/211 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV56334927; called by muse, mutect2, varscan2
- HSF2 | c.804T>G p.N268K | Missense Mutation (SNP) | VAF 70/184 reads (38%) | SIFT tolerated (0.69); PolyPhen benign (0.029); catalogued as COSV63773783; called by muse, mutect2, varscan2
- HSPD1 | c.1208T>G p.V403G | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV61443412; called by muse, mutect2, varscan2
- HSPG2 | c.8166C>T p.A2722= | Splice Region (SNP) | VAF 22/68 reads (32%) | catalogued as rs141870522; called by muse, mutect2, varscan2
- HTR3D | c.1097G>A p.G366E (on ENST00000382489 / NM_001163646.2; = p.G191E on NM_182537.3) | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0.096); catalogued as rs764286325, COSV61913836; called by mutect2, varscan2
- HTT | c.364C>T p.Q122* | Nonsense Mutation (SNP) | VAF 89/173 reads (51%) | catalogued as COSV61860453; called by muse, mutect2, varscan2
- HTT | c.3239C>T p.P1080L | Missense Mutation (SNP) | VAF 161/1065 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61860461, COSV61862041; called by muse, mutect2, varscan2
- HTT | c.8615C>T p.S2872F | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); catalogued as COSV61860473; called by muse, mutect2
- IARS1 | c.3625G>A p.G1209S | Missense Mutation (SNP) | VAF 79/187 reads (42%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.231); catalogued as COSV65114780; called by muse, mutect2, varscan2
- IARS2 | c.2269C>A p.Q757K | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.913); catalogued as COSV56958991; called by muse, mutect2, varscan2
- IDI2 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as rs61738901, COSV52987214; called by muse, mutect2, varscan2
- IFT20 | c.10G>A p.D4N | Missense Mutation (SNP) | VAF 50/83 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); catalogued as COSV56876277; called by muse, mutect2, varscan2
- IGDCC4 | c.3718G>A p.G1240S | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.001); catalogued as COSV61536279; called by muse, mutect2, varscan2
- IGKV1-5 | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 53/182 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.168); catalogued as rs572409474; called by muse, mutect2, varscan2
- IGSF10 | c.6619G>A p.D2207N | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746962859, COSV56375498; called by muse, mutect2, varscan2
- IGSF10 | c.4658C>T p.P1553L | Missense Mutation (SNP) | VAF 47/155 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.652); catalogued as rs778934816, COSV56783977; called by muse, mutect2, varscan2
- IGSF11 | c.1208C>T p.S403F (on ENST00000393775 / NM_001015887.3; = p.S402F on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs1559863374, COSV61168376; called by muse, mutect2, varscan2
- IGSF3 | c.3302C>T p.S1101L (on ENST00000369486 / NM_001007237.3; = p.S1121L on NM_001542.4) | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as COSV59589316; called by muse, mutect2, varscan2
- IL10RA | c.537+2T>A p.X179_splice | Splice Site (SNP) | VAF 27/35 reads (77%) | catalogued as rs752569550, COSV57140224; called by muse, mutect2, varscan2
- IL1R1 | c.1512A>T p.K504N | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV52105701; called by muse, mutect2, varscan2
- IL20 | c.316C>T p.L106F | Missense Mutation (SNP) | VAF 262/359 reads (73%) | SIFT tolerated (0.18); PolyPhen benign (0.096); catalogued as COSV65584472; called by muse, mutect2, varscan2
- IL31 | c.11A>C p.H4P | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV65476208; called by muse, mutect2, varscan2
- IL36B | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.069); catalogued as COSV52085425; called by muse, mutect2, varscan2
- IL6R | c.422C>T p.S141F | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59815194; called by muse, varscan2
- IL7R | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as COSV57407595; called by muse, varscan2
- ILDR1 | c.414G>A p.W138* | Nonsense Mutation (SNP) | VAF 25/66 reads (38%) | catalogued as COSV56549512; called by muse, mutect2, varscan2
- IMPG2 | c.1514G>A p.R505K | Missense Mutation (SNP) | VAF 47/172 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV51976556; called by muse, mutect2, varscan2
- INSR | c.3647C>T p.S1216F | Missense Mutation (SNP) | VAF 71/186 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.031); catalogued as rs757264298, COSV57160757; called by muse, mutect2, varscan2
- INTS1 | c.3559C>T p.Q1187* | Nonsense Mutation (SNP) | VAF 31/356 reads (9%) | catalogued as COSV67177098; called by muse, mutect2
- IP6K1 | c.331G>C p.E111Q | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as COSV58663374; called by muse, mutect2, varscan2
- IPO11 | c.1079C>T p.P360L | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.035); catalogued as COSV57575161; called by muse, mutect2, varscan2
- IRF6 | c.1016G>A p.R339K | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as CM081673, COSV65419147; called by muse, mutect2, varscan2
- IRX2 | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.154); catalogued as rs749462859, COSV57410659; called by muse, mutect2, varscan2
- ITGA8 | c.2627A>G p.Q876R | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.124); catalogued as COSV65227335; called by muse, mutect2, varscan2
- ITLN1 | c.514G>A p.D172N | Missense Mutation (SNP) | VAF 92/142 reads (65%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as COSV58274035; called by muse, mutect2, varscan2
- ITPRID1 | c.1351G>A p.G451R | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0.022); catalogued as rs369485544; called by muse, mutect2, varscan2
- JAG1 | c.1553C>T p.S518F | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54755825; called by muse, mutect2, varscan2
- JAKMIP2 | c.1860G>A p.M620I | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV54601927; called by muse, mutect2, varscan2
- JMY | c.2453C>T p.P818L | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as rs778673068, COSV68660549; called by muse, mutect2, varscan2
- JPH2 | c.1954A>G p.K652E | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.017); catalogued as COSV65902868; called by muse, mutect2, varscan2
- KALRN | c.7972G>A p.E2658K (on ENST00000360013 / NM_001024660.4; = p.E961K on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/153 reads (29%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.364); catalogued as COSV52250857; called by muse, mutect2, varscan2
- KATNIP | c.1486A>C p.T496P | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV55178446; called by muse, mutect2, varscan2
- KBTBD12 | c.683C>T p.S228F | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); catalogued as COSV59678893; called by muse, mutect2, varscan2
- KCNA4 | c.1843G>A p.E615K | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.119); catalogued as COSV60251676; called by muse, mutect2, varscan2
- KCNB1 | c.2350C>T p.P784S | Missense Mutation (SNP) | VAF 124/446 reads (28%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.031); catalogued as rs898902576, COSV65567347; called by muse, mutect2, varscan2
- KCNB1 | c.2138T>C p.L713P | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.017); catalogued as rs1246186475, COSV65567355; called by muse, mutect2, varscan2
- KCNC3 | c.1037C>T p.P346L | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV65386746; called by muse, mutect2, varscan2
- KCNH3 | c.3146G>A p.G1049E | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); catalogued as rs867584076, COSV57790350; called by muse, mutect2, varscan2
- KCNH4 | c.418G>A p.G140R | Missense Mutation (SNP) | VAF 26/36 reads (72%) | SIFT deleterious (0.05); PolyPhen benign (0.025); catalogued as COSV52916708, COSV99236785; called by muse, mutect2, varscan2
- KCNK17 | c.939G>A p.M313I | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.003); catalogued as COSV64685162; called by muse, mutect2, varscan2
- KCNK2 | c.115A>C p.T39P (on ENST00000444842 / NM_001017425.3; = p.T24P on NM_014217.4) | Missense Mutation (SNP) | VAF 56/74 reads (76%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.221); catalogued as COSV67204876; called by muse, mutect2, varscan2
- KCTD5 | c.461T>G p.V154G | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT tolerated (0.32); PolyPhen benign (0.122); catalogued as COSV57064262; called by muse, mutect2, varscan2
- KDR | c.1033G>A p.G345R | Missense Mutation (SNP) | VAF 45/258 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55773482; called by muse, mutect2, varscan2
- KIAA0319 | c.3053G>A p.R1018Q | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as rs757441676, COSV65497680; called by muse, mutect2, varscan2
- KIAA0513 | c.773G>A p.R258K | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50740961; called by muse, mutect2, varscan2
- KIAA1109 | c.1271T>A p.M424K | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV52668927, COSV99145361; called by muse, mutect2, varscan2
- KIAA1109 | c.9166G>A p.G3056R | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52668956, COSV52684819; called by muse, mutect2, varscan2
- KIAA1109 | c.12613C>T p.L4205F | Missense Mutation (SNP) | VAF 39/75 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV52668972; called by muse, mutect2, varscan2
- KIAA1522 | c.1562C>T p.P521L (on ENST00000373480 / NM_001198972.2; = p.P580L on NM_020888.3) | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53863655; called by muse, mutect2, varscan2
- KIAA1614 | c.1969C>T p.H657Y | Missense Mutation (SNP) | VAF 46/57 reads (81%) | SIFT tolerated (0.8); PolyPhen possibly damaging (0.693); catalogued as COSV62550721; called by muse, mutect2, varscan2
- KIF13A | c.1004A>G p.N335S | Missense Mutation (SNP) | VAF 80/367 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV52447780; called by muse, mutect2, varscan2
- KIF1B | c.4040C>T p.S1347F (on ENST00000377086 / NM_001365952.1; = p.S1301F on NM_015074.3) | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.703); catalogued as rs1427984416, COSV55807262; called by muse, mutect2, varscan2
- KLB | c.478C>T p.P160S | Missense Mutation (SNP) | VAF 58/194 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as COSV57301160; called by muse, mutect2, varscan2
- KLC4 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as rs756928667, COSV52434917; called by muse, varscan2
- KLC4 | c.1769C>T p.S590F | Missense Mutation (SNP) | VAF 26/173 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV52434952; called by muse, mutect2, varscan2
- KLF17 | c.406G>A p.G136R | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as rs749005256, COSV64856171; called by muse, mutect2, varscan2
- KLHDC7B | c.998G>A p.R333Q (on ENST00000395676; = p.R974Q on NM_138433.5) | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs994476289, COSV67464467; called by muse, varscan2
- KLHL22 | c.1141C>T p.Q381* | Nonsense Mutation (SNP) | VAF 11/42 reads (26%) | catalogued as COSV61020543; called by muse, mutect2, varscan2
- KLHL24 | c.968G>A p.R323Q | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.487); catalogued as rs547446710, COSV54425693; called by muse, mutect2, varscan2
- KLHL38 | c.1378T>C p.F460L | Missense Mutation (SNP) | VAF 47/273 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV58086892; called by muse, mutect2, varscan2
- KLHL6 | c.131G>A p.G44E | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as rs768036930, COSV58065727; called by muse, mutect2, varscan2
- KMT2D | c.6085C>T p.P2029S | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56413809; called by muse, mutect2, varscan2
- KMT2E | c.4249C>T p.P1417S | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0); catalogued as COSV57572018; called by muse, mutect2, varscan2
- KNG1 | c.1372G>A p.G458R | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.028); catalogued as COSV53977241; called by muse, mutect2, varscan2
- KRT25 | c.616C>T p.Q206* | Nonsense Mutation (SNP) | VAF 84/141 reads (60%) | catalogued as COSV56444483; called by muse, mutect2, varscan2
- KRT37 | c.209C>T p.P70L | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs776480029, COSV56657707; called by muse, mutect2, varscan2
- KRT6B | c.1379T>G p.V460G | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52883133; called by muse, mutect2, varscan2
- KRT6C | c.1161G>A p.M387I | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.159); catalogued as rs747710925, COSV52876893; called by muse, mutect2, varscan2
- KRT7 | c.1206-1G>A p.X402_splice | Splice Site (SNP) | VAF 14/66 reads (21%) | catalogued as rs1461104782, COSV57766026; called by muse, mutect2, varscan2
- KRT79 | c.1121G>A p.G374E | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV57939468; called by muse, mutect2, varscan2
- KRT8 | c.1448A>T p.K483M | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV53176882; called by muse, mutect2, varscan2
- KRTAP19-8 | c.152C>T p.P51L | Missense Mutation (SNP) | VAF 42/160 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.112); catalogued as COSV66998375; called by muse, mutect2, varscan2
- L1TD1 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.665); catalogued as COSV63133389; called by muse, mutect2, varscan2
- LACC1 | c.1072C>T p.P358S | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); catalogued as rs1332158784, COSV57828951; called by muse, mutect2, varscan2
- LARS1 | c.3203C>T p.S1068F (on ENST00000394434 / NM_020117.11; = p.S1041F on NM_016460.3) | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV50974303; called by muse, mutect2, varscan2
- LDHA | c.214C>T p.L72F | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.07); catalogued as COSV57039641; called by muse, mutect2, varscan2
- LHCGR | c.1063G>A p.D355N | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV54292805; called by muse, mutect2, varscan2
- LHX2 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 19/23 reads (83%) | SIFT deleterious (0.04); PolyPhen benign (0.359); catalogued as rs1303464139, COSV65318097; called by muse, mutect2, varscan2
- LHX4 | c.611G>A p.W204* | Nonsense Mutation (SNP) | VAF 42/239 reads (18%) | catalogued as COSV55374642; called by muse, mutect2, varscan2
- LHX9 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 38/175 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.437); catalogued as COSV61327931; called by muse, mutect2, varscan2
- LILRB1 | c.587G>A p.G196E (on ENST00000427581; = p.G160E on NM_006669.6) | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); catalogued as rs866926837; called by muse, varscan2
- LILRB1 | c.956C>T p.T319I (on ENST00000427581; = p.T283I on NM_006669.6) | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.112); catalogued as COSV61119590; called by muse, varscan2
- LILRB2 | c.1675G>A p.D559N | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV58744506; called by muse, mutect2, varscan2
- LILRB2 | c.33C>T p.L11= | Splice Region (SNP) | VAF 36/125 reads (29%) | catalogued as rs1178785149, COSV58744513; called by muse, mutect2, varscan2
- LIMK2 | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.363); catalogued as rs765703194, COSV59182110; called by muse, mutect2, varscan2
- LIN7A | c.415C>T p.P139S | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs866830191, COSV54020298; called by muse, mutect2, varscan2
- LIX1L | c.532C>T p.P178S | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1165769024, COSV63417104; called by muse, mutect2, varscan2
- LRBA | c.5003C>T p.P1668L | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.026); catalogued as rs760323448, COSV63953194; called by muse, mutect2, varscan2
- LRFN2 | c.503C>T p.S168F | Missense Mutation (SNP) | VAF 30/153 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV57826126; called by muse, varscan2
- LRP1B | c.12172G>A p.D4058N | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV67206505, COSV67283723; called by muse, mutect2, varscan2
- LRP1B | c.4729C>T p.L1577F | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV67197912, COSV67221199; called by muse, mutect2, varscan2
- LRP5 | c.286G>A p.G96R | Missense Mutation (SNP) | VAF 80/182 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.695); catalogued as COSV53714124; called by muse, mutect2, varscan2
- LRRC1 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 37/209 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.111); catalogued as COSV63823516; called by muse, mutect2, varscan2
- LRRC34 | c.1289C>T p.S430F (on ENST00000446859 / NM_001172779.2; = p.S398F on NM_153353.5) | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.073); catalogued as COSV57185972; called by muse, mutect2, varscan2
- LRRC4B | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.585); catalogued as COSV65349718; called by muse, mutect2, varscan2
- LRRIQ1 | c.2278C>T p.Q760* | Nonsense Mutation (SNP) | VAF 82/291 reads (28%) | catalogued as COSV67829154; called by muse, mutect2, varscan2
- LRRK2 | c.2375G>A p.R792K | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1177435115, COSV54149917; called by muse, mutect2, varscan2
- LRRN1 | c.1559T>C p.L520P | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.898); catalogued as COSV60013433; called by muse, mutect2, varscan2
- LRRTM1 | c.1247G>A p.G416D | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.62); PolyPhen benign (0.024); catalogued as COSV54440187; called by muse, mutect2, varscan2
- LRTM1 | c.520C>T p.L174F | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.617); catalogued as rs142832767; called by muse, mutect2, varscan2
- LSAMP | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (0.54); PolyPhen benign (0.407); catalogued as COSV61285917; called by muse, mutect2, varscan2
- LSM14B | c.296C>T p.S99F | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs1358506729, COSV53379826; called by muse, mutect2, varscan2
- LY75 | c.4817C>T p.S1606F | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.314); catalogued as COSV55104369; called by muse, mutect2, varscan2
- LY75 | c.3565G>A p.E1189K | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as COSV55104397, COSV99716113; called by muse, mutect2, varscan2
- MACF1 | c.3580G>A p.E1194K | Missense Mutation (SNP) | VAF 49/136 reads (36%) | catalogued as COSV58368919; called by muse, mutect2, varscan2
- MACF1 | c.7834G>A p.E2612K | Missense Mutation (SNP) | VAF 26/69 reads (38%) | catalogued as COSV57117073; called by muse, mutect2, varscan2
- MAD1L1 | c.1181C>T p.A394V | Missense Mutation (SNP) | VAF 29/210 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV56232050; called by muse, mutect2, varscan2
- MAGEA1 | c.553G>A p.D185N | Missense Mutation (SNP) | VAF 47/55 reads (85%) | SIFT tolerated (0.21); PolyPhen benign (0.133); catalogued as COSV63118430; called by muse, mutect2, varscan2
- MARCHF11 | c.752G>A p.G251E | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1473774361, COSV60127649; called by muse, mutect2, varscan2
- MARCO | c.560G>A p.G187E | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs1394987980, COSV59053641; called by muse, mutect2, varscan2
- MAS1L | c.418G>A p.G140R | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.55); PolyPhen benign (0.014); catalogued as rs779464226, COSV65808794; called by muse, mutect2, varscan2
- MATN2 | c.2740G>A p.D914N | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.999); catalogued as rs770743517, COSV54709609; called by mutect2, varscan2
- MBD5 | c.1048C>T p.P350S | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.582); catalogued as COSV68696558; called by muse, mutect2, varscan2
- MED12L | c.2134C>T p.P712S | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56370234, COSV99851498; called by muse, mutect2, varscan2
- MEP1A | c.436G>A p.G146R | Missense Mutation (SNP) | VAF 34/173 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.369); catalogued as COSV57919402; called by muse, varscan2
- MEP1A | c.511G>A p.D171N | Missense Mutation (SNP) | VAF 52/398 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57919406; called by muse, varscan2
- MFN1 | c.1229C>T p.S410L | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV54938833; called by muse, mutect2, varscan2
- MFSD4A | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 123/171 reads (72%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.593); catalogued as COSV65656343; called by muse, mutect2, varscan2
- MFSD6L | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61002565; called by muse, mutect2, varscan2
- MGRN1 | c.211C>T p.P71S | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1014474091, COSV52150181; called by muse, mutect2, varscan2
- MIA3 | c.293C>T p.P98L | Missense Mutation (SNP) | VAF 402/626 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60511902; called by muse, mutect2, varscan2
- MICAL2 | c.2785-1G>A p.X929_splice | Splice Site (SNP) | VAF 13/48 reads (27%) | catalogued as COSV56319271; called by muse, mutect2, varscan2
- MISP | c.337C>T p.P113S | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as COSV53119582; called by muse, mutect2, varscan2
- MISP | c.458G>A p.R153K | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.013); catalogued as rs1318812605; called by mutect2, varscan2
- MMP24 | c.767C>T p.T256I | Missense Mutation (SNP) | VAF 39/178 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs999960638, COSV55769433; called by muse, mutect2, varscan2
- MORC1 | c.2632G>A p.E878K | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as rs549951203, COSV51714451; called by muse, mutect2, varscan2
- MORC1 | c.1821A>T p.E607D | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV51717974; called by muse, mutect2, varscan2
- MORC1 | c.1742C>T p.S581F | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.364); catalogued as COSV51717985; called by muse, mutect2, varscan2
- MOV10L1 | c.2071-1G>A p.X691_splice | Splice Site (SNP) | VAF 89/160 reads (56%) | catalogued as COSV53169881; called by muse, varscan2
- MPEG1 | c.1960G>A p.G654R | Missense Mutation (SNP) | VAF 43/127 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as COSV57089761; called by muse, mutect2, varscan2
- MPIG6B | c.559G>A p.E187K (on ENST00000649779 / NM_138272.3; = p.R193Q on NM_025260.4) | Missense Mutation (SNP) | VAF 79/612 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.311); catalogued as rs762417052, COSV65389573; called by muse, mutect2, varscan2
- MROH7 | c.1550C>T p.S517F | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1352054394, COSV100273799, COSV59868065; called by muse, mutect2, varscan2
- MRTFB | c.2446C>T p.Q816* (on ENST00000571589 / NM_001365412.2; = p.Q766* on NM_014048.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 32/79 reads (41%) | catalogued as COSV57957289; called by muse, mutect2, varscan2
- MTHFD1 | c.1305G>A p.M435I | Missense Mutation (SNP) | VAF 66/140 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53699553; called by muse, mutect2, varscan2
- MTHFD1L | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV66208340; called by muse, mutect2, varscan2
- MTMR8 | c.799C>T p.R267C | Missense Mutation (SNP) | VAF 28/32 reads (88%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs777686067, COSV66393270; called by muse, mutect2, varscan2
- MUC16 | c.26954C>T p.A8985V | Missense Mutation (SNP) | VAF 64/154 reads (42%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.047); catalogued as COSV67459465; called by muse, mutect2, varscan2
- MUC16 | c.26579C>T p.S8860F | Missense Mutation (SNP) | VAF 42/84 reads (50%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.307); catalogued as COSV67459477; called by muse, mutect2, varscan2
- MUC16 | c.25903G>A p.D8635N | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.451); catalogued as COSV67459484; called by muse, mutect2, varscan2
- MUC16 | c.24613G>A p.D8205N | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.047); catalogued as COSV67459495; called by muse, mutect2, varscan2
- MUC16 | c.18940G>A p.E6314K | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.549); catalogued as COSV67457320; called by muse, mutect2, varscan2
- MUC16 | c.10330C>T p.P3444S | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.033); catalogued as rs1413168534, COSV67459517; called by muse, mutect2, varscan2
- MUC16 | c.9629G>A p.S3210N | Missense Mutation (SNP) | VAF 63/124 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.782); catalogued as COSV67459522; called by muse, mutect2, varscan2
- MUC16 | c.8491G>A p.E2831K | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); catalogued as COSV67459539; called by muse, mutect2, varscan2
- MUC16 | c.1484C>T p.S495F | Missense Mutation (SNP) | VAF 38/68 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.354); catalogued as COSV67459554; called by muse, mutect2, varscan2
- MUC17 | c.12187C>T p.P4063S | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV60285727; called by muse, mutect2, varscan2
- MUC4 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.301); catalogued as COSV62143731; called by muse, mutect2, varscan2
- MUC5AC | c.13954G>A p.E4652K | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT deleterious (0.01); catalogued as COSV64369469; called by muse, mutect2, varscan2
- MUC7 | c.1046C>T p.S349L | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.918); catalogued as COSV59217979; called by muse, mutect2, varscan2
- MX2 | c.969G>A p.M323I | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as COSV58096067; called by muse, mutect2, varscan2
- MX2 | c.1873G>A p.E625K | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV58094801; called by muse, mutect2, varscan2
- MXRA5 | c.4204G>A p.E1402K | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as rs1428747814, COSV54224157; called by muse, mutect2, varscan2
- MYBPC3 | c.2809G>A p.G937R | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); catalogued as COSV57025960; called by muse, mutect2, varscan2
- MYCBP2 | c.2420C>T p.P807L (on ENST00000357337; = p.P845L on NM_015057.5) | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.981); catalogued as COSV62015302; called by muse, mutect2, varscan2
- MYH10 | c.1068T>G p.F356L | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.77); PolyPhen benign (0.013); catalogued as COSV52598847; called by muse, mutect2, varscan2
- MYH3 | c.3607G>A p.E1203K | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1223550924, COSV56863529; called by muse, mutect2, varscan2
- MYH4 | c.3550G>A p.E1184K | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV55116251; called by muse, mutect2, varscan2
- MYH8 | c.4179G>A p.K1393= | Splice Region (SNP) | VAF 8/28 reads (29%) | catalogued as COSV67960432; called by muse, mutect2
- MYO16 | c.3235C>T p.P1079S | Missense Mutation (SNP) | VAF 48/123 reads (39%) | SIFT tolerated (0.4); PolyPhen probably damaging (1); catalogued as rs1043293046, COSV62748807; called by muse, mutect2, varscan2
- MYO18B | c.2990C>T p.P997L | Missense Mutation (SNP) | VAF 38/72 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.178); catalogued as COSV100124319, COSV59131269; called by muse, mutect2, varscan2
- MYO18B | c.7643C>A p.P2548Q | Missense Mutation (SNP) | VAF 10/12 reads (83%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.592); catalogued as COSV59131290; called by muse, varscan2
- MYO5B | c.1058C>T p.P353L | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as COSV53216187; called by muse, mutect2, varscan2
- MYO6 | c.814C>T p.R272W | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1303908885, COSV64118608; called by muse, mutect2, varscan2
- MYOCD | c.835C>T p.P279S | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58501714; called by muse, mutect2, varscan2
- MYOCD | c.1783G>A p.E595K | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT tolerated (0.53); PolyPhen benign (0.169); catalogued as rs538701790, COSV58501741; called by muse, mutect2, varscan2
- NADK | c.115C>T p.R39W | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as rs755581382, COSV58271293; called by muse, varscan2
- NAT10 | c.495+1G>A p.X165_splice | Splice Site (SNP) | VAF 63/88 reads (72%) | catalogued as COSV57662466, COSV57663194; called by muse, mutect2, varscan2
- NAV3 | c.3406C>T p.R1136C | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57060679; called by muse, mutect2, varscan2
- NAV3 | c.4105C>T p.L1369F | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57074109, COSV57079560; called by muse, mutect2, varscan2
- NAV3 | c.7102G>A p.E2368K (on ENST00000397909 / NM_001024383.2; = p.E2346K on NM_014903.6) | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as rs756005980, COSV57074126; called by mutect2, varscan2
- NBR1 | c.574C>T p.P192S | Missense Mutation (SNP) | VAF 46/166 reads (28%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV57831880; called by muse, mutect2, varscan2
- NCOR1 | c.6206C>T p.S2069F | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.043); catalogued as COSV51970582; called by muse, mutect2, varscan2
- NDST1 | c.46C>T p.P16S | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.17); catalogued as COSV55786557; called by muse, mutect2, varscan2
- NDUFB2 | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as COSV52595248; called by muse, mutect2, varscan2
- NEB | c.8395C>T p.R2799C | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs779321118, COSV51103103; called by muse, mutect2, varscan2
- NEBL | c.2107G>A p.E703K | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as rs866858799, COSV65802441; called by muse, mutect2, varscan2
- NEGR1 | c.1047G>T p.K349N | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.161); catalogued as COSV100166674, COSV60840769; called by muse, mutect2
- NEGR1 | c.518G>A p.R173Q | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs752419911, COSV60838953, COSV60848356; called by muse, mutect2, varscan2
- NEUROD6 | c.157G>A p.G53R | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.47); PolyPhen benign (0.037); catalogued as COSV51771011; called by muse, mutect2, varscan2
- NGRN | c.496G>A p.G166S | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.435); catalogued as COSV58960908; called by muse, mutect2, varscan2
- NHS | c.3568G>A p.G1190R | Missense Mutation (SNP) | VAF 49/55 reads (89%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.837); catalogued as rs1569320603, COSV66273739; called by muse, mutect2, varscan2
- NKX2-2 | c.490C>T p.L164F | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV65819396; called by muse, mutect2, varscan2
- NLGN4Y | c.797C>T p.S266F | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59295395; called by muse, mutect2, varscan2
- NLRP1 | c.3916-1G>A p.X1306_splice (on ENST00000572272 / NM_033004.4; = p.X1262_splice on NM_014922.5) | Splice Site (SNP) | VAF 15/41 reads (37%) | catalogued as COSV52565589; called by muse, mutect2, varscan2
- NLRP11 | c.2503G>A p.E835K | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.038); catalogued as rs759776521, COSV64086722, COSV64088690; called by muse, mutect2, varscan2
- NLRP12 | c.137G>A p.G46E | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60746046; called by muse, mutect2, varscan2
- NLRP9 | c.2437G>A p.D813N | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.436); catalogued as COSV60460008; called by muse, mutect2, varscan2
- NMT1 | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as rs778948844, COSV51959263; called by muse, mutect2, varscan2
- NMUR1 | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.051); catalogued as COSV59403977; called by muse, mutect2, varscan2
- NOTCH4 | c.968C>T p.P323L | Missense Mutation (SNP) | VAF 60/356 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV66680024; called by muse, mutect2, varscan2
- NPAS4 | c.1255G>A p.D419N | Missense Mutation (SNP) | VAF 51/113 reads (45%) | SIFT tolerated (0.46); PolyPhen benign (0.037); catalogued as COSV60649253; called by muse, mutect2, varscan2
- NPNT | c.986C>T p.P329L | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.141); catalogued as COSV59753104; called by muse, mutect2, varscan2
- NPY5R | c.1181A>T p.N394I | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV58451662; called by muse, mutect2, varscan2
- NR4A3 | c.5C>T p.P2L | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58244051, COSV58244536; called by muse, mutect2, varscan2
- NRIP1 | c.3233C>T p.S1078F | Missense Mutation (SNP) | VAF 38/192 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV59656536, COSV59656704; called by muse, mutect2, varscan2
- NRK | c.450del p.E151Kfs*15 | Frame Shift Del (DEL) | VAF 16/25 reads (64%) | catalogued as COSV54597238; called by mutect2, pindel, varscan2
- NRROS | c.326G>A p.S109N | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as COSV100145639, COSV60745460; called by muse, mutect2, varscan2
- NSG2 | c.320A>T p.Y107F | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.973); catalogued as COSV57457494; called by muse, mutect2, varscan2
- NT5C1B | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.006); catalogued as rs1309432516, COSV58395406; called by muse, mutect2, varscan2
- NUP133 | c.1234T>G p.F412V | Missense Mutation (SNP) | VAF 110/160 reads (69%) | SIFT tolerated (0.5); PolyPhen benign (0.015); catalogued as COSV54570199; called by muse, mutect2, varscan2
- NUP210L | c.1914T>G p.C638W | Missense Mutation (SNP) | VAF 61/259 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.094); catalogued as COSV55145799; called by muse, mutect2, varscan2
- NXN | c.716C>T p.S239L | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs747357061, COSV61096174; called by muse, mutect2, varscan2
- OCIAD2 | c.383+1G>A p.X128_splice | Splice Site (SNP) | VAF 55/400 reads (14%) | catalogued as COSV56716506; called by muse, mutect2, varscan2
- OGFR | c.1307C>A p.P436H | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV51698056; called by muse, varscan2
- OGG1 | c.391C>G p.R131G | Missense Mutation (SNP) | VAF 45/178 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100115494, COSV57352395; called by muse, mutect2, varscan2
- ONECUT2 | c.509C>T p.P170L | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.19); catalogued as rs778610599, COSV72203310; called by muse, mutect2
- OPN4 | c.259G>A p.G87S | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1488620070, COSV54115041, COSV54115721; called by muse, mutect2, varscan2
- OPRK1 | c.920C>T p.A307V | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated (0.55); PolyPhen benign (0.06); catalogued as COSV55569729; called by muse, mutect2, varscan2
- OPRPN | c.382C>T p.P128S | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV68192781; called by muse, varscan2
- OR10H5 | c.934C>T p.P312S | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as COSV100454794, COSV58277876; called by muse, varscan2
- OR10K2 | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 71/175 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59220965; called by muse, mutect2, varscan2
- OR11A1 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 17/180 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as rs373751127; called by muse, mutect2
- OR2A4 | c.49C>T p.P17S | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV59575814; called by muse, varscan2
- OR2A5 | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1453662925, COSV68738635; called by muse, mutect2, varscan2
- OR2B2 | c.998A>T p.N333I | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as COSV57579447; called by muse, mutect2, varscan2
- OR2J2 | c.932G>A p.G311E | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs865981126, COSV65847911; called by muse, mutect2, varscan2
- OR2L13 | c.694G>A p.G232R | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as COSV63551105, COSV63551708; called by muse, mutect2, varscan2
- OR2M3 | c.917G>A p.G306E | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV71758986; called by muse, mutect2, varscan2
- OR2T1 | c.626C>T p.P209L | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV63541677; called by muse, mutect2, varscan2
- OR2T27 | c.122G>A p.S41N | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as COSV61281521; called by mutect2, varscan2
- OR4N5 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 72/163 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV61320065; called by muse, mutect2, varscan2
- OR51S1 | c.851C>T p.S284F | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs755927864, COSV59057361; called by muse, mutect2, varscan2
- OR52E4 | c.454G>A p.G152R | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as COSV57624430; called by muse, mutect2, varscan2
- OR5H2 | c.284G>A p.R95K | Missense Mutation (SNP) | VAF 54/165 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62350560, COSV62351802; called by muse, mutect2, varscan2
- OR5H2 | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV62350566, COSV62352078; called by muse, mutect2, varscan2
- OR6C76 | c.692G>A p.R231K | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.278); catalogued as COSV100094342, COSV60388905; called by muse, mutect2, varscan2
- OR6K3 | c.973G>A p.V325M (on ENST00000368146; = p.V309M on NM_001005327.2) | Missense Mutation (SNP) | VAF 28/171 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.027); catalogued as COSV63745518, COSV63745968; called by muse, mutect2, varscan2
- OR6K3 | c.626C>T p.S209F (on ENST00000368146; = p.S193F on NM_001005327.2) | Missense Mutation (SNP) | VAF 49/200 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.25); catalogued as COSV63745521; called by muse, mutect2, varscan2
- OR6Q1 | c.681G>A p.W227* | Nonsense Mutation (SNP) | VAF 53/108 reads (49%) | catalogued as COSV56932861; called by muse, varscan2
- OR7D2 | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.001); catalogued as rs753509176, COSV60138781; called by muse, mutect2, varscan2
- OR7G2 | c.533T>A p.L178H | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV59687742; called by mutect2, varscan2
- OR8H3 | c.220T>A p.Y74N | Missense Mutation (SNP) | VAF 90/585 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57908402, COSV57910823; called by muse, mutect2, varscan2
- OR8J1 | c.889G>A p.D297N | Missense Mutation (SNP) | VAF 20/188 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as rs1460614300, COSV57317694; called by muse, varscan2
- OR9Q1 | c.85C>T p.L29F | Missense Mutation (SNP) | VAF 45/205 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.022); catalogued as rs1384281162, COSV100110491, COSV59039252; called by muse, mutect2, varscan2
- OSBPL3 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.37); PolyPhen benign (0.263); catalogued as rs1319448412, COSV57655354; called by muse, mutect2, varscan2
- OSR1 | c.404G>A p.G135D | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.018); catalogued as rs1018830654, COSV55345110; called by muse, mutect2, varscan2
- OTUD4 | c.1310C>T p.S437F (on ENST00000447906 / NM_001366057.1; = p.S372F on NM_001102653.1) | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.264); catalogued as COSV71381755; called by muse, mutect2, varscan2
- OXCT2 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.51); catalogued as COSV59593651, COSV59594073; called by muse, mutect2, varscan2
- P2RX3 | c.1135G>A p.D379N | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs771077034, COSV54442146; called by mutect2, varscan2
- P2RX7 | c.826C>T p.R276C | Missense Mutation (SNP) | VAF 102/404 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs769736394; called by muse, mutect2, varscan2
- P2RY1 | c.560T>A p.L187H | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59309283; called by mutect2, varscan2
- PADI4 | c.175A>C p.K59Q | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.354); catalogued as COSV64923776; called by muse, mutect2, varscan2
- PAPSS1 | c.557C>T p.T186I | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.063); catalogued as COSV54488595; called by muse, mutect2, varscan2
- PAPSS2 | c.799C>T p.P267S | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63263123; called by muse, mutect2, varscan2
- PARP8 | c.1810C>T p.R604* | Nonsense Mutation (SNP) | VAF 52/174 reads (30%) | catalogued as COSV55858788, COSV55867093; called by muse, mutect2, varscan2
- PC | c.2707G>A p.D903N | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.767); catalogued as rs758910766, COSV58992474; called by muse, mutect2, varscan2
- PCDH12 | c.2013G>A p.W671* | Nonsense Mutation (SNP) | VAF 17/42 reads (40%) | catalogued as COSV51520796; called by muse, varscan2
- PCDH18 | c.2854G>A p.E952K | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.985); catalogued as rs375254105, COSV61267580; called by muse, mutect2, varscan2
- PCDH9 | c.3694C>A p.P1232T (on ENST00000377865 / NM_203487.3; = p.P1198T on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.981); catalogued as rs1056768671, COSV60542549; called by muse, mutect2, varscan2
- PCDHA12 | c.977G>A p.G326E | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV56493212; called by muse, mutect2, varscan2
- PCDHA5 | c.764C>T p.P255L | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.108); catalogued as COSV65351270; called by muse, mutect2, varscan2
- PCDHB12 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 84/207 reads (41%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.044); catalogued as rs1554286731, COSV53395359; called by muse, mutect2, varscan2
- PCDHB4 | c.352G>A p.G118R | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); catalogued as COSV52021633; called by muse, mutect2, varscan2
- PCDHB9 | c.605G>A p.R202Q | Missense Mutation (SNP) | VAF 99/251 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.856); catalogued as rs782097852, COSV53377701; called by muse, mutect2, varscan2
- PCLO | c.14471C>T p.P4824L | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as rs1437232168, COSV61627999; called by muse, mutect2
- PCLO | c.13168G>A p.D4390N | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.993); catalogued as COSV61628009; called by muse, mutect2, varscan2
- PCLO | c.5903C>T p.S1968L | Missense Mutation (SNP) | VAF 49/114 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.182); catalogued as rs748624623, COSV61628016; called by muse, mutect2, varscan2
- PDE4D | c.521C>T p.S174F (on ENST00000340635 / NM_001104631.2; = p.S38F on NM_006203.4) | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.809); catalogued as COSV58952023; called by muse, mutect2, varscan2
- PDE6A | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 51/111 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV54924151; called by muse, mutect2, varscan2
- PDE7B | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.705); catalogued as rs906155870, COSV57495667; called by muse, mutect2, varscan2
- PDGFRA | c.1288G>A p.G430R | Missense Mutation (SNP) | VAF 24/185 reads (13%) | SIFT tolerated (0.82); PolyPhen benign (0.025); catalogued as rs1197237938, COSV57267024; called by muse, mutect2, varscan2
- PDP2 | c.35C>T p.S12F | Missense Mutation (SNP) | VAF 47/268 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.006); catalogued as COSV61240405; called by muse, mutect2, varscan2
- PDS5A | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57824404; called by muse, mutect2, varscan2
- PDZD2 | c.1187C>T p.S396F | Missense Mutation (SNP) | VAF 51/82 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56856071; called by muse, mutect2, varscan2
- PDZD3 | c.1636G>A p.A546T (on ENST00000531114; = p.A466T on NM_024791.4) | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs1239880531, COSV59539455; called by muse, mutect2, varscan2
- PEG3 | c.4213G>A p.E1405K | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.452); catalogued as rs1343303675, COSV55630571; called by muse, mutect2, varscan2
- PEG3 | c.495G>A p.W165* | Nonsense Mutation (SNP) | VAF 10/23 reads (43%) | catalogued as COSV55630584; called by muse, mutect2, varscan2
- PEX1 | c.1645C>T p.P549S | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as rs1053943553, COSV50396685; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PEX6 | c.1969G>A p.G657S | Missense Mutation (SNP) | VAF 32/216 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.03); catalogued as COSV55102710; called by muse, mutect2, varscan2
- PFAS | c.5C>T p.S2F | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as COSV58979656; called by muse, mutect2, varscan2
- PGD | c.416C>T p.P139L | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV54621078, COSV99581058; called by muse, mutect2, varscan2
- PGP | c.876T>G p.N292K | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.636); catalogued as COSV57027582; called by muse, mutect2
- PHACTR3 | c.464G>A p.G155E | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV63026870; called by muse, mutect2, varscan2
- PHF24 | c.455G>A p.R152K | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.99); catalogued as COSV54273955; called by muse, mutect2, varscan2
- PHKA1 | c.3400C>T p.L1134F | Missense Mutation (SNP) | VAF 21/24 reads (88%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59804677; called by muse, mutect2, varscan2
- PHLPP2 | c.1712C>T p.P571L | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.999); catalogued as COSV62423868; called by muse, mutect2, varscan2
- PIGR | c.1801G>A p.D601N | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs267598334, COSV62903711; called by muse, mutect2, varscan2
- PKLR | c.788G>A p.G263E | Missense Mutation (SNP) | VAF 23/32 reads (72%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as rs867384868, COSV61360955; called by muse, mutect2, varscan2
- PLA1A | c.522G>A p.M174I | Missense Mutation (SNP) | VAF 36/140 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV56331315, COSV99846027; called by muse, mutect2, varscan2
1,138 further variants in this file (452 protein-altering or splice-affecting, 659 silent, 27 other) are not listed here.
